Somatic mutation profile of cancer-model specimen HCM-WCMC-0747-C50-85P (3D Organoid; aliquot HCM-WCMC-0747-C50-85P-01D-A88H-36), derived from the primary tumor of HCMI case HCM-WCMC-0747-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 43.2 years (15,793 days).
Specimen HCM-WCMC-0747-C50-85P: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 749ffc18-bf03-484d-9f6a-1becd75db41f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0747-C50-10A (Blood Derived Normal), aliquot HCM-WCMC-0747-C50-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3ca82a9-3608-47b2-a9a2-5073d2329bea

The open-access MAF lists 6,652 somatic variants for this specimen: 5,041 protein-altering or splice-affecting, 1,326 silent, 285 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4,322, Silent 1,326, Nonsense Mutation 622, Intron 185, Splice Site 39, Splice Region 34, 3'UTR 33, RNA 23, 5'Flank 20, Frame Shift Ins 16, 3'Flank 15, 5'UTR 9.

Variants (750 of 6,652; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.3661C>T p.R1221C | Missense Mutation (SNP) | VAF 212/430 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63751215, CM030401; ClinVar: pathogenic; called by muse, varscan2
- ARG1 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 192/411 reads (47%) | catalogued as rs104893940, CM920106; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ASPM | c.9319C>T p.R3107* | Nonsense Mutation (SNP) | VAF 84/274 reads (31%) | catalogued as rs199422187, CM092387, COSV54123750; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASPM | c.4732C>T p.R1578* | Nonsense Mutation (SNP) | VAF 105/389 reads (27%) | catalogued as rs753406334, COSV54125634; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BMPR1A | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 136/342 reads (40%) | catalogued as rs587782400, CM014516, COSV64404910; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BMPR2 | c.2533G>T p.E845* | Nonsense Mutation (SNP) | VAF 181/372 reads (49%) | catalogued as rs1085307394, CM1313679; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CACNA1F | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 185/457 reads (40%) | catalogued as rs797044676, CM010174, COSV59903636; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDH1 | c.1137G>A p.T379= | Splice Region (SNP) | VAF 123/123 reads (100%) | catalogued as rs587783050, CS060517, COSV55733400; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.4294C>T p.R1432* | Nonsense Mutation (SNP) | VAF 161/315 reads (51%) | catalogued as rs587779585, CM013250, COSV58591606; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNMT1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 135/279 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs751093624, COSV61576638; called by muse, mutect2, varscan2
- DYNC2LI1 | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 97/228 reads (43%) | catalogued as rs745930390, CM157152, COSV53182974; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EPHB4 | c.1180C>T p.R394* | Nonsense Mutation (SNP) | VAF 182/479 reads (38%) | catalogued as rs994651018, COSV62268365; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 182/391 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1258412021, COSV54063404, COSV54077108; called by muse, mutect2, varscan2
- FLNA | c.3596C>T p.S1199L | Missense Mutation (SNP) | VAF 352/741 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs28935473, CM030673, COSV61040824; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.4198C>T p.R1400* | Nonsense Mutation (SNP) | VAF 165/335 reads (49%) | catalogued as rs775112258, CM1311877, COSV70350217; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MERTK | c.2180G>A p.R727Q | Missense Mutation (SNP) | VAF 135/300 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs878853354, CM148731, COSV54927455; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- MGA | c.3724C>T p.R1242* | Nonsense Mutation (SNP) | VAF 145/332 reads (44%) | hotspot (GDC flag); catalogued as COSV54948051; called by muse, mutect2, varscan2
- MSH6 | c.3964G>T p.E1322* | Nonsense Mutation (SNP) | VAF 87/173 reads (50%) | catalogued as rs1553333707, CM1412053, COSV52274101; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 92/212 reads (43%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCDH15 | c.3316C>T p.R1106* | Nonsense Mutation (SNP) | VAF 159/328 reads (48%) | catalogued as rs202033121, CM094636; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 103/271 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 167/352 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 45/365 reads (12%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 181/332 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PSMD12 | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 59/140 reads (42%) | catalogued as rs1114167442, COSV62065273; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.4934G>A p.R1645Q (on ENST00000303395 / NM_001202435.3; = p.R1634Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 180/402 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121917976, CM072001, CM1511233, COSV57662283; ClinVar: pathogenic; called by muse, varscan2
- SPTA1 | c.4975C>T p.R1659* | Nonsense Mutation (SNP) | VAF 103/358 reads (29%) | catalogued as rs1394141324, CM085728, COSV100935534; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SYNJ1 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 127/286 reads (44%) | catalogued as rs1569075471, COSV59145375; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TMEM126A | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 204/451 reads (45%) | catalogued as rs121434508, CM092006, COSV58735100; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TUBA1A | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 149/321 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as rs886039513, CM145649, COSV55497204; ClinVar: pathogenic; called by muse, mutect2, varscan2
- WAC | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 91/189 reads (48%) | catalogued as rs886041614, COSV61567179; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 152/321 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV55285440; called by muse, mutect2, varscan2
- A4GALT | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 183/431 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs762477967; called by muse, mutect2, varscan2
- AADAC | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 118/267 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV99233421; called by muse, mutect2, varscan2
- ABCA10 | c.1582T>G p.L528V | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV52228238; called by muse, mutect2, varscan2
- ABCA3 | c.1554C>A p.Y518* | Nonsense Mutation (SNP) | VAF 229/476 reads (48%) | catalogued as COSV57052448; called by muse, mutect2, varscan2
- ABCA4 | c.6070G>A p.D2024N | Missense Mutation (SNP) | VAF 160/440 reads (36%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.794); catalogued as rs747011478, COSV100933043; called by muse, mutect2, varscan2
- ABCA6 | c.3704C>A p.S1235Y | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV52646517; called by muse, mutect2, varscan2
- ABCA8 | c.3440C>A p.S1147Y | Missense Mutation (SNP) | VAF 81/180 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.396); catalogued as COSV104393298; called by muse, mutect2, varscan2
- ABCB11 | c.3278C>T p.S1093L | Missense Mutation (SNP) | VAF 26/651 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs1030004521, COSV99793428; called by muse, mutect2
- ABCB6 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 188/378 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.54); catalogued as rs147046586; called by muse, mutect2, varscan2
- ABCC2 | c.2933C>T p.S978L | Missense Mutation (SNP) | VAF 32/430 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs763988128, COSV64984835; called by muse, mutect2
- ABCC8 | c.471C>A p.F157L | Missense Mutation (SNP) | VAF 193/390 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV56848000; called by muse, mutect2, varscan2
- ABCE1 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 105/224 reads (47%) | catalogued as COSV56846807; called by muse, mutect2, varscan2
- ABCG2 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 131/257 reads (51%) | catalogued as rs201034377, COSV52948355; called by muse, mutect2, varscan2
- ABHD12B | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 101/188 reads (54%) | catalogued as rs909563542; called by muse, mutect2, varscan2
- ABHD16B | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 219/485 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV53863610; called by muse, mutect2, varscan2
- ABHD4 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 175/423 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs755342789, COSV53530796; called by muse, mutect2, varscan2
- ABHD5 | c.819G>T p.K273N (on ENST00000458276 / NM_001365650.1; = p.E336* on NM_016006.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 129/256 reads (50%) | catalogued as rs762662276, CM122662; called by muse, mutect2, varscan2
- ABHD6 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 138/375 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.02); catalogued as rs754217725, COSV55908871; called by muse, mutect2, varscan2
- ABL2 | c.2050G>A p.E684K (on ENST00000502732 / NM_007314.4; = p.E669K on NM_005158.5) | Missense Mutation (SNP) | VAF 197/792 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); catalogued as COSV61012829; called by muse, mutect2, varscan2
- AC069544.2 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 99/192 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV65683908; called by muse, mutect2, varscan2
- AC092835.1 | c.806G>T p.R269I | Missense Mutation (SNP) | VAF 33/465 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV69921576; called by muse, mutect2
- AC098582.1 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 139/347 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs771388611; called by muse, mutect2, varscan2
- AC099489.1 | c.4237G>A p.A1413T | Missense Mutation (SNP) | VAF 134/272 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs777140143; called by muse, mutect2, varscan2
- AC126283.2 | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 97/280 reads (35%) | catalogued as COSV67097984, COSV67099039; called by muse, mutect2, varscan2
- AC231657.3 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 176/339 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.868); catalogued as rs782678518; called by muse, mutect2, varscan2
- ACAA2 | c.440C>A p.S147Y | Missense Mutation (SNP) | VAF 108/222 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.03); catalogued as rs1322908376; called by mutect2, varscan2
- ACADM | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs769906625, COSV63720304; called by muse, mutect2, varscan2
- ACAP2 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 135/288 reads (47%) | catalogued as rs897760774; called by muse, mutect2, varscan2
- ACAP3 | c.543G>T p.K181N | Missense Mutation (SNP) | VAF 212/411 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV61223726; called by muse, mutect2, varscan2
- ACBD4 | c.659G>A p.R220H (on ENST00000376955 / NM_001378111.1; = p.P223= on NM_024722.4) | Missense Mutation (SNP) | VAF 215/469 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs557303418; called by muse, mutect2, varscan2
- ACE | c.1177G>T p.G393C | Missense Mutation (SNP) | VAF 210/488 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52013980; called by muse, mutect2
- ACKR2 | c.967C>A p.L323M | Missense Mutation (SNP) | VAF 218/524 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99825515; called by mutect2, varscan2
- ACO1 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199823143, COSV59378955; called by muse, mutect2, varscan2
- ACO2 | c.330C>A p.F110L | Missense Mutation (SNP) | VAF 184/535 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.973); catalogued as COSV53442098, COSV53443395; called by muse, mutect2, varscan2
- ACOT12 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 188/459 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs772516081; called by muse, mutect2, varscan2
- ACOT8 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 190/448 reads (42%) | catalogued as COSV99467338; called by muse, mutect2, varscan2
- ACRBP | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 209/450 reads (46%) | catalogued as COSV57523840, COSV57524678; called by muse, mutect2, varscan2
- ACSM2B | c.1449G>T p.M483I | Missense Mutation (SNP) | VAF 170/356 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100312656; called by muse, mutect2, varscan2
- ACSM2B | c.1201G>A p.V401I | Missense Mutation (SNP) | VAF 121/267 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs576087006, COSV100313142; called by muse, mutect2, varscan2
- ACSM5 | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 162/365 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs369151501; called by muse, mutect2, varscan2
- ACSS1 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 158/347 reads (46%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs752186614; called by muse, mutect2, varscan2
- ACTC1 | c.360G>T p.K120N | Missense Mutation (SNP) | VAF 153/364 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.925); catalogued as COSV51760211; called by muse, mutect2, varscan2
- ACTN2 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 217/642 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV104426763, COSV63978633; called by muse, mutect2, varscan2
- ACTN2 | c.2632G>A p.A878T | Missense Mutation (SNP) | VAF 210/626 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1270659015; called by muse, mutect2, varscan2
- ACTN3 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 208/397 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1232811519, COSV72207678; called by muse, mutect2, varscan2
- ACTR1A | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 176/418 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV64024400; called by muse, varscan2
- ACTR5 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 103/242 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as rs768469393; called by muse, mutect2, varscan2
- ACVR1 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 132/293 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55116621; called by muse, mutect2, varscan2
- ADAL | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 82/224 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1344077571; called by muse, mutect2, varscan2
- ADAM15 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 238/775 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.79); catalogued as rs754878868, COSV99665288; called by muse, mutect2, varscan2
- ADAM18 | c.1068T>G p.I356M | Missense Mutation (SNP) | VAF 99/206 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as rs201596679; called by muse, mutect2, varscan2
- ADAMTS12 | c.540G>T p.K180N | Missense Mutation (SNP) | VAF 175/378 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.21); catalogued as rs146144250; called by muse, mutect2, varscan2
- ADAMTS16 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 121/314 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.809); catalogued as COSV56999397, COSV99941133; called by muse, mutect2, varscan2
- ADAMTS18 | c.2705G>A p.R902Q | Missense Mutation (SNP) | VAF 98/98 reads (100%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as rs144292157; called by muse, varscan2
- ADAMTS18 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 129/129 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as rs775057284, COSV51408503; called by muse, mutect2, varscan2
- ADAMTS20 | c.2335C>A p.L779I | Missense Mutation (SNP) | VAF 89/177 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV101166252; called by muse, mutect2, varscan2
- ADAMTS9 | c.2530C>T p.R844C | Missense Mutation (SNP) | VAF 153/316 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs759664813, COSV55774765; called by muse, mutect2, varscan2
- ADAR | c.3477G>T p.K1159N | Missense Mutation (SNP) | VAF 137/472 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1268794909, COSV52714157; called by muse, mutect2, varscan2
- ADCK1 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 204/434 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs748957337, COSV99452248; called by muse, mutect2, varscan2
- ADD3 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 93/179 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs767558945, COSV53321083; called by muse, mutect2, varscan2
- ADGRB3 | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 157/360 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs779693752; called by muse, mutect2, varscan2
- ADGRD1 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 19/419 reads (5%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.138); catalogued as COSV55445873; called by muse, mutect2
- ADGRF1 | c.124C>A p.L42I | Missense Mutation (SNP) | VAF 101/213 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV64800624; called by muse, mutect2, varscan2
- ADGRF5 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 182/382 reads (48%) | catalogued as COSV51937265; called by muse, mutect2, varscan2
- ADGRG4 | c.5974C>A p.L1992I | Missense Mutation (SNP) | VAF 271/533 reads (51%) | SIFT tolerated (0.42); PolyPhen benign (0.033); catalogued as COSV54950689; called by muse, mutect2, varscan2
- ADGRG7 | c.786C>A p.F262L | Missense Mutation (SNP) | VAF 190/352 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751437270, COSV56301212, COSV99840688; called by muse, mutect2, varscan2
- ADGRL2 | c.2518G>T p.D840Y (on ENST00000370717 / NM_001366005.1; = p.D827Y on NM_012302.4) | Missense Mutation (SNP) | VAF 69/161 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs1189334334, COSV54677538; called by muse, mutect2, varscan2
- ADGRL3 | c.2599C>T p.P867S (on ENST00000506720 / NM_001322402.2; = p.P799S on NM_015236.6) | Missense Mutation (SNP) | VAF 15/266 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72231428; called by muse, mutect2
- ADGRL3 | c.3002G>A p.R1001Q (on ENST00000506720 / NM_001322402.2; = p.R933Q on NM_015236.6) | Missense Mutation (SNP) | VAF 83/241 reads (34%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.888); catalogued as rs370040630; called by muse, mutect2, varscan2
- ADGRL4 | c.25G>T p.V9F | Missense Mutation (SNP) | VAF 85/169 reads (50%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs547554975, COSV66064053; called by muse, mutect2, varscan2
- ADGRV1 | c.7007G>A p.R2336Q | Missense Mutation (SNP) | VAF 174/342 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs755180090; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.7771G>A p.E2591K | Missense Mutation (SNP) | VAF 178/376 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs757315634, COSV67978987; called by muse, mutect2, varscan2
- ADGRV1 | c.9481C>A p.P3161T | Missense Mutation (SNP) | VAF 121/229 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV67991519; called by muse, mutect2, varscan2
- ADH6 | c.29G>A p.C10Y | Missense Mutation (SNP) | VAF 93/203 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52955267; called by muse, mutect2, varscan2
- ADIPOR2 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 185/379 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.023); catalogued as rs200483941, COSV63946468; called by muse, mutect2, varscan2
- ADNP2 | c.2243G>A p.R748Q | Missense Mutation (SNP) | VAF 178/355 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); catalogued as rs377757808; called by muse, mutect2, varscan2
- ADRA1D | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 302/589 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as rs1405319810; called by muse, mutect2, varscan2
- ADRA2B | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 81/626 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as rs758303353, COSV69787374; called by muse, mutect2, varscan2
- ADRB2 | c.826G>T p.G276C | Missense Mutation (SNP) | VAF 254/525 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60005280; called by muse, mutect2, varscan2
- AFF2 | c.302C>A p.S101Y | Missense Mutation (SNP) | VAF 203/404 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60664320; called by mutect2, varscan2
- AFG3L2 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 96/219 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs765665699; called by muse, mutect2, varscan2
- AGAP2 | c.2189G>A p.R730Q (on ENST00000547588 / NM_001122772.2; = p.R394Q on NM_014770.4) | Missense Mutation (SNP) | VAF 225/464 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs867161743, COSV57731334; called by muse, mutect2, varscan2
- AGBL5 | c.80C>A p.S27Y | Missense Mutation (SNP) | VAF 209/417 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV100549432; called by muse, mutect2, varscan2
- AGBL5 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 189/460 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs143744999; called by muse, mutect2, varscan2
- AGL | c.2591G>A p.R864Q | Missense Mutation (SNP) | VAF 152/314 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.079); catalogued as rs776599112, CM140956, COSV54048187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGMAT | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 153/370 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs768542408, COSV65435781; called by muse, mutect2
- AGMO | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as rs1273447604, COSV61105744; called by muse, mutect2, varscan2
- AGO4 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 171/427 reads (40%) | catalogued as COSV64617106; called by muse, mutect2, varscan2
- AGPAT3 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 201/202 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV52367458; called by muse, mutect2, varscan2
- AGPS | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 101/183 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51560637, COSV51563645; called by muse, mutect2, varscan2
- AGRN | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 288/575 reads (50%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.964); catalogued as rs143976046; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHCTF1 | c.2519C>A p.S840Y (on ENST00000366508; = p.S814Y on NM_015446.5) | Missense Mutation (SNP) | VAF 68/308 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100403755; called by muse, mutect2, varscan2
- AHNAK | c.6985G>T p.D2329Y | Missense Mutation (SNP) | VAF 211/443 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99945396; called by muse, mutect2, varscan2
- AHNAK | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 251/539 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs745885352, COSV99947730; called by muse, mutect2, varscan2
- AHNAK2 | c.10651G>A p.G3551S | Missense Mutation (SNP) | VAF 160/412 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as rs199591478; called by muse, mutect2, varscan2
- AHRR | c.574G>T p.D192Y | Missense Mutation (SNP) | VAF 176/438 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100327991; called by muse, mutect2, varscan2
- AKAP13 | c.4088C>T p.S1363L | Missense Mutation (SNP) | VAF 138/298 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as rs911991539; called by muse, mutect2, varscan2
- AKAP6 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 181/487 reads (37%) | catalogued as rs1335831849; called by muse, mutect2, varscan2
- AKIRIN2 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 104/234 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs947958170; called by muse, mutect2, varscan2
- AKR1B15 | c.666G>T p.E222D | Missense Mutation (SNP) | VAF 150/498 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV71152860; called by mutect2, varscan2
- AKR1E2 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 110/244 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs768333050, COSV53630547; called by muse, mutect2, varscan2
- AKR7L | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 158/320 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs186763608; called by muse, mutect2, varscan2
- AL035461.3 | c.2768G>A p.R923Q | Missense Mutation (SNP) | VAF 89/199 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.515); catalogued as rs778702816; called by muse, mutect2, varscan2
- AL592490.1 | c.2311G>A p.D771N | Missense Mutation (SNP) | VAF 235/450 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69425764; called by muse, mutect2, varscan2
- AL592490.1 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 180/394 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as rs866867581, COSV69424742, COSV69427786; called by muse, mutect2
- ALDH1B1 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 219/488 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs770780314, COSV66620189; called by muse, varscan2
- ALKBH6 | c.118C>T p.R40* (on ENST00000252984 / NM_001297701.2; = p.R68* on NM_032878.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/314 reads (5%) | catalogued as rs1247337824, COSV53323984; called by muse, mutect2
- ALPK2 | c.5632C>A p.L1878I | Missense Mutation (SNP) | VAF 136/371 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV64498227; called by muse, mutect2, varscan2
- ALYREF | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 259/567 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.053); catalogued as rs1567861648; called by muse, mutect2, varscan2
- AMDHD1 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 160/349 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201031842; called by muse, mutect2, varscan2
- AMER1 | c.2642G>A p.R881Q | Missense Mutation (SNP) | VAF 345/654 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as rs372769953, COSV57668176, COSV57671832; called by muse, mutect2, varscan2
- AMER1 | c.929G>A p.S310N | Missense Mutation (SNP) | VAF 292/586 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs200339567; called by muse, varscan2
- AMFR | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 196/196 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV51920352; called by muse, mutect2, varscan2
- AMIGO3 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 229/464 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV57537835; called by muse, mutect2, varscan2
- AMN1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as rs1307903772, COSV55673219; called by muse, mutect2
- AMN1 | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 103/242 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV55670827; called by muse, mutect2, varscan2
- AMN1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 121/269 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.233); catalogued as rs765159439, COSV55670682; called by muse, mutect2, varscan2
- ANAPC4 | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 94/196 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59543328; called by muse, mutect2, varscan2
- ANGPT2 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV100290422; called by muse, varscan2
- ANGPTL7 | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 184/380 reads (48%) | SIFT tolerated (0.65); PolyPhen benign (0.068); catalogued as COSV63872036; called by mutect2, varscan2
- ANK2 | c.10925G>A p.R3642Q | Missense Mutation (SNP) | VAF 327/327 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757939990, COSV52166643; called by muse, mutect2, varscan2
- ANK3 | c.2738+7C>T | Splice Region (SNP) | VAF 222/517 reads (43%) | catalogued as rs754349234; called by muse, mutect2, varscan2
- ANKAR | c.1122G>T p.E374D | Missense Mutation (SNP) | VAF 108/223 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV55617775; called by muse, mutect2, varscan2
- ANKFN1 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 137/283 reads (48%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs761277860, COSV59456319; called by muse, mutect2, varscan2
- ANKRD26 | c.3058C>T p.R1020C | Missense Mutation (SNP) | VAF 119/267 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.731); catalogued as rs761804757; called by muse, mutect2, varscan2
- ANKRD28 | c.2143C>T p.R715W | Missense Mutation (SNP) | VAF 188/442 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs202220330; called by muse, mutect2, varscan2
- ANKRD31 | c.1997G>A p.G666E | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs866314475; called by muse, varscan2
- ANKRD31 | c.1400G>A p.G467E | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV57159418; called by muse, mutect2, varscan2
- ANKRD36 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.846); catalogued as rs946488323, COSV70736234; called by muse, mutect2, varscan2
- ANKRD36B | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 64/481 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as rs750175150; called by muse, mutect2, varscan2
- ANKRD46 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 91/190 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs773423022; called by muse, mutect2, varscan2
- ANKRD62 | c.608T>G p.F203C | Missense Mutation (SNP) | VAF 76/143 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.369); catalogued as COSV58409849; called by muse, mutect2, varscan2
- ANKS1A | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 97/241 reads (40%) | catalogued as COSV64461030; called by muse, mutect2, varscan2
- ANKS6 | c.1994T>C p.L665S | Missense Mutation (SNP) | VAF 168/369 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1249605155; called by muse, mutect2, varscan2
- ANLN | c.2047G>T p.E683* | Nonsense Mutation (SNP) | VAF 71/181 reads (39%) | catalogued as COSV56078070; called by muse, mutect2, varscan2
- ANO8 | c.884C>T p.S295L | Missense Mutation (SNP) | VAF 231/540 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV50174155; called by muse, mutect2, varscan2
- ANOS1 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 229/503 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); catalogued as rs1404298787, COSV52916162; called by muse, mutect2, varscan2
- ANP32E | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 118/312 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.183); catalogued as rs782603651, COSV58481542; called by muse, mutect2, varscan2
- ANTXR1 | c.818C>A p.S273Y | Missense Mutation (SNP) | VAF 132/285 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as rs747143387, COSV58023545; called by muse, mutect2, varscan2
- ANXA13 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 140/341 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as rs201212750, COSV51623085, COSV51626415; called by muse, mutect2, varscan2
- AOC2 | c.2118C>A p.F706L (on ENST00000253799 / NM_009590.4; = p.F679L on NM_001158.5) | Missense Mutation (SNP) | VAF 239/530 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs772005140, COSV53824129, COSV53826096; called by muse, mutect2, varscan2
- AP000721.1 | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 257/544 reads (47%) | PolyPhen probably damaging (0.937); catalogued as COSV100034331; called by mutect2, varscan2
- AP1AR | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 155/348 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as rs367798505; called by muse, mutect2, varscan2
- AP2A1 | c.2592C>A p.F864L | Missense Mutation (SNP) | VAF 169/334 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV58242275; called by muse, mutect2, varscan2
- APBA1 | c.2190G>T p.K730N | Missense Mutation (SNP) | VAF 156/310 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99595980, COSV99597291; called by mutect2, varscan2
- APOB | c.9849C>A p.F3283L | Missense Mutation (SNP) | VAF 241/444 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV51936132; called by muse, mutect2, varscan2
- APOB | c.1931C>A p.S644Y | Missense Mutation (SNP) | VAF 121/267 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs147173587, COSV51922803, COSV51933707; called by muse, mutect2, varscan2
- APOBEC3F | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 159/352 reads (45%) | catalogued as rs773563808, COSV100415089; called by muse, mutect2, varscan2
- APOD | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 145/301 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs150503831; called by muse, mutect2, varscan2
- APOL1 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 138/359 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs752305718, COSV100045985; called by muse, mutect2, varscan2
- APOL5 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 300/576 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs887484530; called by muse, mutect2, varscan2
- ARAP1 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 212/553 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.013); catalogued as rs373473025; called by muse, mutect2, varscan2
- ARAP2 | c.4871G>A p.R1624Q | Missense Mutation (SNP) | VAF 226/501 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs1249697981, COSV58292022; called by muse, mutect2, varscan2
- ARAP2 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778125188; called by muse, mutect2, varscan2
- AREG | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 119/220 reads (54%) | catalogued as rs1283640826; called by muse, mutect2, varscan2
- ARHGAP11A | c.1294C>T p.R432* | Nonsense Mutation (SNP) | VAF 80/200 reads (40%) | catalogued as rs1487117985, COSV64381180; called by muse, varscan2
- ARHGAP26 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 188/380 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1191015382, COSV50835979; called by muse, mutect2, varscan2
- ARHGAP29 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 80/216 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53110295, COSV99558207; called by muse, mutect2, varscan2
- ARHGAP36 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 183/417 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.15); catalogued as rs866578619, COSV99357958; called by muse, mutect2, varscan2
- ARHGAP4 | c.1530G>T p.E510D | Missense Mutation (SNP) | VAF 175/369 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV63133250, COSV63134924; called by muse, mutect2, varscan2
- ARHGDIB | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 127/296 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.196); catalogued as rs774401441, COSV56763076; called by muse, mutect2, varscan2
- ARHGEF10 | c.2012A>G p.D671G (on ENST00000398564; = p.D646G on NM_014629.4) | Missense Mutation (SNP) | VAF 194/406 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1446957268; called by muse, mutect2, varscan2
- ARHGEF17 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 297/656 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as rs1226836790; called by muse, mutect2, varscan2
- ARHGEF17 | c.3394C>T p.R1132W | Missense Mutation (SNP) | VAF 261/545 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as rs1285187269; called by muse, mutect2, varscan2
- ARHGEF25 | c.1511G>T p.R504I | Missense Mutation (SNP) | VAF 268/547 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV99677913; called by muse, mutect2, varscan2
- ARHGEF3 | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 208/436 reads (48%) | catalogued as COSV99575465; called by muse, mutect2, varscan2
- ARID4A | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 112/288 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs1180580215, COSV62161861; called by muse, mutect2, varscan2
- ARL14 | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 172/358 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as COSV57899577; called by muse, varscan2
- ARL6 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.013); catalogued as COSV60117242; called by muse, mutect2, varscan2
- ARMC2 | c.2252G>A p.R751H | Missense Mutation (SNP) | VAF 166/350 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as rs377734728; called by muse, mutect2, varscan2
- ARMC9 | c.372G>T p.K124N | Missense Mutation (SNP) | VAF 139/320 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV63020947; called by muse, mutect2, varscan2
- ARPC1A | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 117/261 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs1159010389, COSV99501160; called by muse, mutect2, varscan2
- ARRB2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 245/541 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as rs771693958, COSV99036395; called by muse, mutect2, varscan2
- ARRDC3 | c.362C>T p.T121I | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs779678796; called by muse, mutect2, varscan2
- ARSK | c.1385C>A p.S462Y | Missense Mutation (SNP) | VAF 74/166 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.324); catalogued as COSV66170448; called by muse, mutect2, varscan2
- ASAH1 | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 124/257 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.495); catalogued as COSV50501972, COSV50504395; called by muse, mutect2, varscan2
- ASAP1 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 109/281 reads (39%) | catalogued as COSV100727209; called by muse, mutect2, varscan2
- ASB12 | c.5G>A p.R2K | Missense Mutation (SNP) | VAF 167/337 reads (50%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.001); catalogued as rs745631393, COSV100744608, COSV100744742; called by muse, mutect2, varscan2
- ASB14 | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 133/295 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs758842851, COSV55700742; called by muse, mutect2, varscan2
- ASB15 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 72/194 reads (37%) | catalogued as COSV99306792; called by muse, mutect2, varscan2
- ASH1L | c.4024C>T p.R1342* | Nonsense Mutation (SNP) | VAF 125/423 reads (30%) | catalogued as COSV64213851; called by muse, mutect2, varscan2
- ASMTL | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 252/504 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779211999, COSV101187833; called by muse, varscan2
- ASNS | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 70/145 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV51552598; called by muse, mutect2, varscan2
- ASPM | c.10269G>T p.K3423N | Missense Mutation (SNP) | VAF 72/224 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV104399271; called by mutect2, varscan2
- ASTN2 | c.2183C>T p.S728L (on ENST00000313400 / NM_001365069.1; = p.S677L on NM_014010.5) | Missense Mutation (SNP) | VAF 186/356 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs144736118; called by muse, mutect2, varscan2
- ASXL2 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 33/93 reads (35%) | catalogued as COSV55454380; called by muse, mutect2, varscan2
- ASXL3 | c.1294G>T p.D432Y | Missense Mutation (SNP) | VAF 170/365 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV99323704; called by muse, mutect2, varscan2
- ASXL3 | c.4894G>T p.E1632* | Nonsense Mutation (SNP) | VAF 30/432 reads (7%) | catalogued as COSV52462181, COSV99325833; called by muse, mutect2
- ATAD2 | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 80/246 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs528861654, COSV99784154; called by muse, mutect2, varscan2
- ATAD2 | c.10C>A p.L4I | Missense Mutation (SNP) | VAF 176/407 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as COSV99783984; called by muse, mutect2, varscan2
- ATE1 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 151/304 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs773450449, COSV56435136; called by muse, mutect2, varscan2
- ATF6B | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 158/377 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.644); catalogued as rs199610969; called by muse, mutect2, varscan2
- ATF7IP2 | c.1463C>A p.S488Y | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61092963; called by muse, mutect2
- ATG12 | c.274C>A p.L92I | Missense Mutation (SNP) | VAF 86/229 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.721); catalogued as rs561465491; called by muse, mutect2, varscan2
- ATG2B | c.3922C>T p.R1308C | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.963); catalogued as rs772425977, COSV55890367; called by muse, mutect2, varscan2
- ATP10D | c.2791G>T p.A931S | Missense Mutation (SNP) | VAF 160/348 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56706580; called by muse, mutect2, varscan2
- ATP1A1 | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 141/329 reads (43%) | catalogued as rs759845712; called by muse, mutect2, varscan2
- ATP2A2 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 120/266 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs757914881, CM113597; called by muse, mutect2, varscan2
- ATP2A3 | c.1340G>C p.C447S | Missense Mutation (SNP) | VAF 16/461 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV59231253; called by muse, mutect2
- ATP2B3 | c.2992G>A p.D998N | Missense Mutation (SNP) | VAF 215/458 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs781787078, COSV54850391; called by muse, mutect2, varscan2
- ATP2B3 | c.3115C>T p.L1039F | Missense Mutation (SNP) | VAF 204/441 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.204); catalogued as rs782241469; called by muse, mutect2, varscan2
- ATP5PB | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 175/371 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs751833359, COSV52384704; called by muse, mutect2, varscan2
- ATP6AP2 | c.176C>A p.S59Y | Missense Mutation (SNP) | VAF 155/307 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV101011496, COSV65797177; called by muse, mutect2, varscan2
- ATP7B | c.1870G>T p.E624* | Nonsense Mutation (SNP) | VAF 99/225 reads (44%) | catalogued as COSV54445782; called by muse, mutect2, varscan2
- ATP7B | c.701G>T p.R234I | Missense Mutation (SNP) | VAF 133/330 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV54435370, COSV99666591; called by muse, mutect2, varscan2
- ATP8A1 | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 50/137 reads (36%) | catalogued as rs755553887, COSV100046625; called by muse, mutect2, varscan2
- ATP8A2 | c.3549G>T p.K1183N | Missense Mutation (SNP) | VAF 135/280 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV54939053; called by muse, mutect2, varscan2
- ATP8B1 | c.3041G>A p.R1014Q | Missense Mutation (SNP) | VAF 96/244 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.211); catalogued as rs756828618; called by muse, mutect2, varscan2
- ATP8B3 | c.3488G>A p.S1163N | Missense Mutation (SNP) | VAF 235/498 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs750848646; called by muse, mutect2, varscan2
- ATP8B4 | c.2231C>A p.S744Y | Missense Mutation (SNP) | VAF 123/290 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV52712336; called by muse, mutect2, varscan2
- ATP8B4 | c.1645C>T p.R549* | Nonsense Mutation (SNP) | VAF 72/161 reads (45%) | catalogued as rs940798819, COSV52710402; called by muse, mutect2, varscan2
- ATP8B4 | c.1235G>T p.R412I | Missense Mutation (SNP) | VAF 98/216 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.035); catalogued as COSV52726883; called by mutect2, varscan2
- ATR | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 100/190 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV63384749; called by muse, mutect2, varscan2
- ATRX | c.5386G>T p.D1796Y | Missense Mutation (SNP) | VAF 142/318 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100970229; called by muse, mutect2, varscan2
- ATXN2 | c.3632C>T p.T1211M (on ENST00000550104; = p.T1051M on NM_002973.4) | Missense Mutation (SNP) | VAF 216/467 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs1198968756, COSV57981626; called by muse, mutect2, varscan2
- AXDND1 | c.736A>G p.T246A | Missense Mutation (SNP) | VAF 117/331 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs754536225; called by muse, mutect2, varscan2
- B2M | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 244/552 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs986783978; called by muse, mutect2, varscan2
- B3GAT1 | c.122G>A p.S41N | Missense Mutation (SNP) | VAF 226/437 reads (52%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs756892799; called by muse, mutect2, varscan2
- B3GNT8 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 154/489 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs769114165; called by muse, mutect2, varscan2
- B4GALNT2 | c.200G>T p.R67I | Missense Mutation (SNP) | VAF 126/248 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs777942057; called by muse, mutect2, varscan2
- BAAT | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 27/504 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.699); catalogued as rs747460084; called by muse, mutect2
- BACH1 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 94/236 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750785692, COSV54518596; called by muse, varscan2
- BAHCC1 | c.6304G>A p.E2102K | Missense Mutation (SNP) | VAF 138/338 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.287); catalogued as rs782409877; called by muse, mutect2, varscan2
- BAIAP2L2 | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 54/781 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.588); catalogued as rs747393218; called by muse, mutect2
- BAIAP2L2 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 166/482 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs551506196, COSV59270922; called by muse, mutect2, varscan2
- BANK1 | c.2005C>T p.L669F | Missense Mutation (SNP) | VAF 123/276 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.145); catalogued as COSV59840312; called by muse, mutect2, varscan2
- BARD1 | c.2221G>T p.D741Y | Missense Mutation (SNP) | VAF 197/424 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.832); catalogued as rs587780029, COSV53616112; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAZ1A | c.4508C>T p.S1503L | Missense Mutation (SNP) | VAF 96/249 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1389574742, COSV62409622; called by muse, mutect2, varscan2
- BAZ2B | c.6416T>G p.F2139C | Missense Mutation (SNP) | VAF 145/290 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58603397; called by muse, mutect2, varscan2
- BCAS3 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 109/240 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs773183785, COSV101175451; called by muse, mutect2, varscan2
- BCCIP | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 195/426 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751497919, COSV104372773; called by muse, varscan2
- BCL6B | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 154/371 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs751964952, COSV99546933; called by muse, mutect2, varscan2
- BCL7C | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 154/359 reads (43%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs1319181407; called by muse, mutect2, varscan2
- BEND2 | c.1939G>T p.E647* | Nonsense Mutation (SNP) | VAF 150/333 reads (45%) | catalogued as rs1400847250; called by muse, mutect2, varscan2
- BEND4 | c.535C>A p.L179I | Missense Mutation (SNP) | VAF 184/374 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV72468902; called by muse, mutect2, varscan2
- BEX1 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 218/490 reads (44%) | catalogued as COSV101022493; called by muse, mutect2, varscan2
- BEX1 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 271/603 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.165); catalogued as COSV65579974; called by muse, mutect2, varscan2
- BIRC6 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 123/262 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70196110; called by muse, mutect2, varscan2
- BLMH | c.1190C>A p.S397* | Nonsense Mutation (SNP) | VAF 152/284 reads (54%) | catalogued as COSV55585076; called by muse, mutect2, varscan2
- BLZF1 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 111/381 reads (29%) | catalogued as COSV99051517; called by muse, mutect2, varscan2
- BMP15 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 274/652 reads (42%) | catalogued as COSV99399534; called by muse, varscan2
- BMP15 | c.749C>A p.P250H | Missense Mutation (SNP) | VAF 138/314 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV53140815, COSV53141751; called by muse, mutect2, varscan2
- BMP2 | c.678C>A p.F226L | Missense Mutation (SNP) | VAF 162/354 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV66578028; called by muse, varscan2
- BMP7 | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 225/464 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV67780098; called by muse, mutect2, varscan2
- BMPER | c.1793A>G p.Y598C | Missense Mutation (SNP) | VAF 143/303 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as rs1002066204; called by muse, mutect2, varscan2
- BMT2 | c.1032C>A p.F344L | Missense Mutation (SNP) | VAF 97/210 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV51778386; called by muse, mutect2, varscan2
- BNC2 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 207/459 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs756459154, COSV101033320, COSV66149708; called by muse, mutect2, varscan2
- BOD1L1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 146/322 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50015843, COSV99240474; called by muse, mutect2, varscan2
- BPTF | c.3479C>A p.S1160Y | Missense Mutation (SNP) | VAF 113/257 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as COSV58836415; called by muse, mutect2, varscan2
- BRAF | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 122/254 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV56144127; called by muse, mutect2, varscan2
- BRCA2 | c.3775A>C p.S1259R | Missense Mutation (SNP) | VAF 74/165 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.105); catalogued as rs587782071; ClinVar: uncertain significance; called by muse, mutect2
- BRCA2 | c.8018A>C p.K2673T | Missense Mutation (SNP) | VAF 150/267 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66464740; called by muse, mutect2, varscan2
- BRCC3 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 97/229 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV57462323; called by muse, mutect2, varscan2
- BRINP2 | c.2104C>A p.L702I | Missense Mutation (SNP) | VAF 169/515 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV64175866, COSV64180538; called by muse, mutect2, varscan2
- BRINP3 | c.688C>A p.L230M | Missense Mutation (SNP) | VAF 112/368 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66519186; called by muse, mutect2, varscan2
- BRMS1 | c.213C>A p.F71L | Missense Mutation (SNP) | VAF 157/348 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60820270; called by muse, mutect2, varscan2
- BRPF1 | c.1983+7G>A | Splice Region (SNP) | VAF 128/272 reads (47%) | catalogued as rs751452778; called by muse, mutect2, varscan2
- BRWD3 | c.5237G>A p.R1746Q | Missense Mutation (SNP) | VAF 206/432 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.953); catalogued as rs918551619, COSV100956683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRWD3 | c.2242G>T p.E748* | Nonsense Mutation (SNP) | VAF 83/185 reads (45%) | catalogued as COSV64748961, COSV64754484; called by muse, mutect2, varscan2
- BSPH1 | c.19C>A p.L7I | Missense Mutation (SNP) | VAF 138/307 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60413196; called by muse, mutect2, varscan2
- BSPRY | c.991G>T p.D331Y | Missense Mutation (SNP) | VAF 46/584 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs948571051, COSV99031869; called by muse, mutect2
- BTBD7 | c.1561C>T p.R521* | Nonsense Mutation (SNP) | VAF 169/370 reads (46%) | catalogued as rs1017916547, COSV100597990, COSV58285585; called by muse, mutect2, varscan2
- BTK | c.1645G>T p.D549Y | Missense Mutation (SNP) | VAF 155/335 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58123080; called by muse, mutect2, varscan2
- BTK | c.1044G>T p.E348D | Missense Mutation (SNP) | VAF 211/456 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100437735; called by muse, mutect2, varscan2
- BTN1A1 | c.1170G>T p.E390D | Missense Mutation (SNP) | VAF 187/459 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV55069626; called by muse, mutect2, varscan2
- BTNL3 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 254/535 reads (47%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs778473610, COSV61564442; called by muse, mutect2, varscan2
- BTNL9 | c.560G>T p.R187I | Missense Mutation (SNP) | VAF 251/508 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.835); catalogued as COSV59794831, COSV59795131; called by muse, mutect2, varscan2
- BTRC | c.1537C>T p.R513* (on ENST00000370187 / NM_033637.4; = p.R477* on NM_003939.5) | Nonsense Mutation (SNP) | VAF 118/277 reads (43%) | catalogued as rs568788208, COSV64579105; called by muse, mutect2, varscan2
- BUB1B | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 110/254 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755579898, COSV55011588; called by muse, mutect2, varscan2
- BZW1 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 178/354 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV63349698; called by muse, mutect2, varscan2
- C14orf39 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 62/130 reads (48%) | catalogued as COSV100408121; called by muse, mutect2, varscan2
- C16orf89 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 208/444 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.325); catalogued as rs1366296763, COSV60125129; called by muse, varscan2
- C17orf99 | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 222/418 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs980212271; called by muse, mutect2, varscan2
- C17orf99 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 222/478 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as rs948785372; called by muse, varscan2
- C18orf54 | c.626G>T p.R209I | Missense Mutation (SNP) | VAF 99/188 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV55617296; called by muse, varscan2
- C1QB | c.177G>T p.E59D | Missense Mutation (SNP) | VAF 37/306 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.869); catalogued as COSV59246215; called by muse, mutect2, varscan2
- C1QL4 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 257/546 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as rs750966716, COSV57743425; called by muse, mutect2, varscan2
- C1QTNF12 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 232/480 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs369520877; called by muse, mutect2, varscan2
- C1S | c.421G>T p.V141F | Missense Mutation (SNP) | VAF 102/222 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0.018); catalogued as rs782567111; called by mutect2, varscan2
- C1orf112 | c.783G>T p.K261N | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53680777; called by mutect2, varscan2
- C1orf43 | c.578G>A p.R193Q (on ENST00000368521 / NM_001297718.2; = p.R159Q on NM_015449.4) | Missense Mutation (SNP) | VAF 156/407 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1016886052, COSV62965968; called by muse, mutect2, varscan2
- C1orf87 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 240/448 reads (54%) | catalogued as rs147997086, COSV64596556; called by muse, mutect2
- C22orf15 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 175/350 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.088); catalogued as rs1202464682; called by muse, mutect2, varscan2
- C2CD5 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 94/200 reads (47%) | catalogued as COSV61723130, COSV61724471; called by muse, varscan2
- C2CD5 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 198/410 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61722731; called by muse, varscan2
- C2CD5 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 156/310 reads (50%) | catalogued as COSV61727203; called by muse, mutect2, varscan2
- C2orf16 | c.3826G>A p.E1276K | Missense Mutation (SNP) | VAF 125/272 reads (46%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.606); catalogued as rs977013386; called by muse, mutect2
- C3orf14 | c.326C>A p.P109H | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99223865; called by mutect2, varscan2
- C3orf20 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 246/488 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.343); catalogued as rs768861528, COSV53782331, COSV99513234; called by muse, mutect2
- C3orf38 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 137/287 reads (48%) | catalogued as rs1285309231, COSV59627517; called by muse, mutect2, varscan2
- C4orf46 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 148/300 reads (49%) | catalogued as rs749789362, COSV57014249; called by mutect2, varscan2
- C7 | c.983-1G>T p.X328_splice | Splice Site (SNP) | VAF 51/136 reads (38%) | catalogued as rs1202191236, COSV100495965; called by muse, mutect2, varscan2
- C7 | c.1710C>A p.F570L | Missense Mutation (SNP) | VAF 122/242 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV100496155; called by muse, mutect2, varscan2
- C7orf31 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 121/287 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs531648664, COSV52216035; called by muse, mutect2, varscan2
- C8orf48 | c.893C>A p.S298Y | Missense Mutation (SNP) | VAF 109/294 reads (37%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.007); catalogued as COSV52047028; called by muse, mutect2, varscan2
- CAB39L | c.1004C>T p.T335M | Missense Mutation (SNP) | VAF 117/240 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs780505672, COSV61713671; called by muse, mutect2, varscan2
- CACNA1D | c.3622G>A p.E1208K (on ENST00000350061 / NM_001128840.3; = p.E1228K on NM_000720.4) | Missense Mutation (SNP) | VAF 203/429 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55445291; called by muse, mutect2, varscan2
- CACNA1S | c.2167G>A p.D723N | Missense Mutation (SNP) | VAF 86/317 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); catalogued as rs756920981; called by muse, varscan2
- CACNB2 | c.1075G>A p.E359K (on ENST00000324631 / NM_201596.3; = p.E304K on NM_000724.4) | Missense Mutation (SNP) | VAF 117/253 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV56633541; called by muse, mutect2, varscan2
- CACNB4 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 196/378 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs767538753, COSV52399686; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNG6 | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 136/276 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); catalogued as COSV53165592; called by muse, mutect2, varscan2
- CADPS | c.3853C>A p.Q1285K | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV51875117; called by muse, mutect2
- CALCRL | c.87G>T p.E29D | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV66475990, COSV66476528; called by muse, mutect2, varscan2
- CALR3 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 151/338 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs550089146, COSV54168698; called by muse, mutect2, varscan2
- CAMK2G | c.144G>T p.K48N | Missense Mutation (SNP) | VAF 208/442 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as rs761674491, COSV59485330; called by muse, mutect2
- CAMKK1 | c.1019G>A p.G340D | Missense Mutation (SNP) | VAF 172/382 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1279529960; called by muse, mutect2, varscan2
- CAMSAP2 | c.3964C>T p.R1322C (on ENST00000236925 / NM_001297707.2; = p.R1311C on NM_203459.3) | Missense Mutation (SNP) | VAF 121/450 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as rs140682641; called by muse, mutect2, varscan2
- CAPN2 | c.1990C>T p.R664W | Missense Mutation (SNP) | VAF 159/518 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs1010016325, COSV54337515; called by muse, mutect2, varscan2
- CAPN5 | c.1297G>A p.E433K (on ENST00000456580; = p.E393K on NM_004055.5) | Missense Mutation (SNP) | VAF 150/319 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs369845664; called by muse, mutect2, varscan2
- CAPN9 | c.809G>T p.R270I | Missense Mutation (SNP) | VAF 167/579 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as COSV55232544; called by muse, mutect2, varscan2
- CARD6 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs183781648, COSV54569236; called by muse, mutect2, varscan2
- CARD6 | c.1953G>T p.R651S | Missense Mutation (SNP) | VAF 177/418 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs781512982; called by muse, mutect2, varscan2
- CASK | c.1805C>T p.S602L | Missense Mutation (SNP) | VAF 160/311 reads (51%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as rs868537608, COSV59374892; called by muse, mutect2, varscan2
- CASKIN2 | c.1867C>T p.R623W | Missense Mutation (SNP) | VAF 315/591 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs200961448; called by muse, mutect2, varscan2
- CASP7 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 126/299 reads (42%) | catalogued as COSV100614772; called by muse, mutect2, varscan2
- CASP8 | c.212G>T p.R71I | Missense Mutation (SNP) | VAF 127/272 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51846504, COSV99965286, COSV99965729; called by muse, mutect2, varscan2
- CASQ2 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 14/307 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); catalogued as rs1156705851, COSV54773771; called by muse, mutect2
- CBFA2T3 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 35/309 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs764998500, COSV51928371; called by muse, mutect2, varscan2
- CBL | c.2557G>A p.A853T | Missense Mutation (SNP) | VAF 33/722 reads (5%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1393832618; called by muse, mutect2
- CBLN2 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 195/433 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV99504129; called by muse, mutect2, varscan2
- CBWD2 | c.642G>T p.K214N | Missense Mutation (SNP) | VAF 71/146 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52073508; called by mutect2, varscan2
- CBX3 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 70/341 reads (21%) | catalogued as COSV61761318; called by muse, mutect2, varscan2
- CCAR1 | c.3289T>G p.L1097V | Missense Mutation (SNP) | VAF 86/187 reads (46%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.987); catalogued as rs1040189895, COSV99771223; called by muse, mutect2, varscan2
- CCDC102B | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 140/338 reads (41%) | catalogued as rs186843401, COSV60140682; called by muse, mutect2
- CCDC148 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs140798767; called by muse, mutect2, varscan2
- CCDC149 | c.1130C>T p.S377L (on ENST00000635206 / NM_001330643.2; = p.S366L on NM_173463.5) | Missense Mutation (SNP) | VAF 190/411 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.863); catalogued as rs373188183; called by muse, mutect2, varscan2
- CCDC160 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 124/296 reads (42%) | catalogued as COSV66251579; called by muse, mutect2, varscan2
- CCDC168 | c.16274G>T p.R5425I | Missense Mutation (SNP) | VAF 204/435 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV104400445; called by muse, mutect2, varscan2
- CCDC168 | c.13750G>A p.G4584S | Missense Mutation (SNP) | VAF 15/333 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.101); catalogued as rs1200960473; called by muse, mutect2
- CCDC174 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs201187132; called by muse, mutect2, varscan2
- CCDC181 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 130/412 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376964448; called by muse, mutect2, varscan2
- CCDC39 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 106/215 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1458123630, COSV56483732; called by muse, mutect2, varscan2
- CCDC6 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 125/254 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.338); catalogued as COSV54055823; called by muse, mutect2, varscan2
- CCDC88C | c.4703C>T p.S1568L | Missense Mutation (SNP) | VAF 108/257 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.171); catalogued as rs752668368, COSV57796258; called by muse, mutect2, varscan2
- CCKBR | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 262/561 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs773790618, COSV58106563; called by muse, mutect2, varscan2
- CCKBR | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 245/517 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs865919804, COSV58100422; called by muse, mutect2, varscan2
- CCN2 | c.849C>A p.F283L | Missense Mutation (SNP) | VAF 226/460 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63466512; called by muse, mutect2, varscan2
- CCN6 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 81/228 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs140750750, COSV57888796; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCNB2 | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 177/346 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs531597901, COSV55596186; called by muse, mutect2, varscan2
- CCNE1 | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 126/294 reads (43%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as rs774836905; called by muse, mutect2, varscan2
- CCNF | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 129/317 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV99564149; called by muse, mutect2, varscan2
- CCPG1 | c.1181C>T p.T394M | Missense Mutation (SNP) | VAF 190/375 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs753064740; called by muse, mutect2, varscan2
- CCR1 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 25/544 reads (5%) | catalogued as COSV56122260; called by muse, mutect2
- CCR7 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 214/459 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1442842565, COSV55849574; called by muse, mutect2, varscan2
- CCSER1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 110/235 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs745548077, COSV100390706, COSV61437396; called by muse, mutect2, varscan2
- CCSER1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 92/256 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as rs200976407, COSV61406099; called by muse, varscan2
- CCSER2 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 129/257 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs200068948, COSV56512306; called by muse, mutect2, varscan2
- CD101 | c.2314G>A p.D772N | Missense Mutation (SNP) | VAF 244/460 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200228819; called by muse, mutect2, varscan2
- CD180 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 154/310 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1038384169, COSV56516797, COSV56517903; called by muse, mutect2, varscan2
- CD69 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 102/224 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.026); catalogued as rs142870511; called by muse, mutect2, varscan2
- CDC26 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 119/253 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as rs764264213, COSV65252464, COSV65252631; called by muse, mutect2, varscan2
- CDC37 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 280/624 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as rs767381772; called by muse, mutect2, varscan2
- CDC40 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 96/258 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1244226490, COSV57008311; called by muse, mutect2, varscan2
- CDCA5 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 262/513 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1340393208; called by muse, mutect2, varscan2
- CDH16 | c.2080G>A p.D694N | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs757577637; called by muse, mutect2, varscan2
- CDH2 | c.2054C>T p.S685L | Missense Mutation (SNP) | VAF 188/392 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1371255423, COSV99296158; called by muse, mutect2, varscan2
- CDH2 | c.745A>G p.N249D | Missense Mutation (SNP) | VAF 94/232 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.069); catalogued as COSV52297179; called by muse, mutect2, varscan2
- CDH23 | c.1450-1G>A p.X484_splice | Splice Site (SNP) | VAF 142/316 reads (45%) | catalogued as rs747981278; called by muse, mutect2, varscan2
- CDH5 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 139/139 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1342694698; called by muse, mutect2, varscan2
- CDH7 | c.2084G>A p.R695Q | Missense Mutation (SNP) | VAF 186/369 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.598); catalogued as COSV59886164; called by muse, mutect2, varscan2
- CDH9 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 89/254 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as rs531958842, COSV50256671, COSV99162875; called by muse, mutect2, varscan2
- CDK12 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 195/400 reads (49%) | catalogued as COSV101420628; called by muse, mutect2, varscan2
- CDK13 | c.1877G>A p.R626Q | Missense Mutation (SNP) | VAF 94/161 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs1188926859, COSV51696530; called by muse, mutect2, varscan2
- CDK14 | c.725G>A p.R242Q (on ENST00000380050 / NM_001287135.2; = p.R224Q on NM_012395.3) | Missense Mutation (SNP) | VAF 83/201 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1260973082, COSV56030467; called by muse, mutect2, varscan2
- CDK19 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 83/203 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0.34); catalogued as rs953895657; called by muse, mutect2, varscan2
- CDK4 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 106/216 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.069); catalogued as rs373619077, COSV56984381; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4828G>T p.E1610* | Nonsense Mutation (SNP) | VAF 228/512 reads (45%) | catalogued as COSV100575448; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 181/401 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs141387242; called by muse, mutect2, varscan2
- CDK7 | c.91G>T p.D31Y | Missense Mutation (SNP) | VAF 100/217 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56511769, COSV56515140; called by muse, mutect2, varscan2
- CDKL3 | c.1757G>T p.R586I | Missense Mutation (SNP) | VAF 100/229 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as COSV54740468; called by muse, mutect2, varscan2
- CDKL5 | c.1988C>T p.S663L | Missense Mutation (SNP) | VAF 197/367 reads (54%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV66110977; called by muse, mutect2, varscan2
- CDKL5 | c.2369C>A p.S790Y | Missense Mutation (SNP) | VAF 82/162 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.48); catalogued as COSV66114309; called by muse, mutect2, varscan2
- CDNF | c.129C>A p.F43L | Missense Mutation (SNP) | VAF 71/170 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV101012390; called by muse, mutect2, varscan2
- CDRT1 | c.1246C>T p.R416* | Nonsense Mutation (SNP) | VAF 48/151 reads (32%) | catalogued as rs771329616; called by muse, mutect2, varscan2
- CDYL2 | c.1387G>A p.V463M | Missense Mutation (SNP) | VAF 115/163 reads (71%) | SIFT tolerated (0.14); PolyPhen benign (0.35); catalogued as rs202176613; called by muse, mutect2, varscan2
- CEACAM18 | c.644G>T p.R215I | Missense Mutation (SNP) | VAF 135/297 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV101140335; called by muse, varscan2
- CEL | c.642C>A p.F214L (on ENST00000673714; = p.F211L on NM_001807.6) | Missense Mutation (SNP) | VAF 195/417 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV60827156; called by muse, mutect2, varscan2
- CENPE | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 86/190 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs866905901, COSV54378711; called by muse, varscan2
- CENPF | c.86A>C p.K29T | Missense Mutation (SNP) | VAF 183/548 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65273776; called by muse, mutect2, varscan2
- CENPF | c.4602G>T p.E1534D | Missense Mutation (SNP) | VAF 123/441 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.043); catalogued as COSV65273640; called by muse, mutect2, varscan2
- CENPF | c.5911T>C p.S1971P | Missense Mutation (SNP) | VAF 138/406 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV65274736; called by mutect2, varscan2
- CENPS | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 134/323 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs759332241, COSV58364265; called by muse, mutect2, varscan2
- CENPW | c.29G>T p.R10M | Missense Mutation (SNP) | VAF 101/247 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.471); catalogued as COSV100851381; called by muse, mutect2, varscan2
- CEP126 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 114/219 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1432108672, COSV54822807; called by muse, mutect2, varscan2
- CEP126 | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 100/196 reads (51%) | catalogued as COSV54821526; called by muse, mutect2, varscan2
- CEP135 | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 66/123 reads (54%) | catalogued as COSV57260784, COSV99954689; called by muse, mutect2, varscan2
- CEP162 | c.1920C>A p.F640L | Missense Mutation (SNP) | VAF 87/196 reads (44%) | SIFT tolerated (0.81); PolyPhen benign (0.12); catalogued as COSV100003406; called by muse, mutect2, varscan2
- CEP170 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 34/740 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs957369421; called by muse, mutect2
- CEP170 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 90/299 reads (30%) | catalogued as COSV60508726; called by muse, varscan2
- CEP290 | c.3037G>T p.E1013* | Nonsense Mutation (SNP) | VAF 62/142 reads (44%) | catalogued as CM072942, COSV58350039; called by mutect2, varscan2
- CEP350 | c.7202C>A p.S2401Y | Missense Mutation (SNP) | VAF 22/493 reads (4%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); catalogued as COSV62599014; called by muse, mutect2
- CEP41 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 154/363 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1210916591; called by muse, mutect2, varscan2
- CEP44 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs368964236; called by muse, mutect2, varscan2
- CERS3 | c.252G>T p.E84D | Missense Mutation (SNP) | VAF 77/153 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52565563; called by muse, mutect2, varscan2
- CERS4 | c.399C>A p.F133L | Missense Mutation (SNP) | VAF 169/411 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1407588961; called by muse, mutect2, varscan2
- CERS6 | c.104C>G p.A35G | Missense Mutation (SNP) | VAF 197/478 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as COSV59830743; called by muse, mutect2, varscan2
- CERS6 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 16/463 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs982340851; called by muse, mutect2
- CES3 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 234/234 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs376329904, COSV57593280; called by muse, mutect2, varscan2
- CETN2 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 93/213 reads (44%) | catalogued as COSV100938618; called by muse, mutect2, varscan2
- CFAP100 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 141/347 reads (41%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.761); catalogued as rs765883697, COSV61504382; called by muse, varscan2
- CFAP43 | c.3617G>T p.R1206I | Missense Mutation (SNP) | VAF 112/254 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV100829466; called by muse, mutect2, varscan2
- CFAP45 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 215/676 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV100928630; called by muse, mutect2, varscan2
- CFAP47 | c.3817C>T p.P1273S | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as rs1569239441; called by muse, mutect2, varscan2
- CFAP47 | c.4542G>T p.K1514N | Missense Mutation (SNP) | VAF 19/268 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV100545775, COSV57973710; called by muse, mutect2
- CFAP47 | c.5831G>A p.R1944H | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1226317867, COSV66195251; called by muse, varscan2
- CFAP53 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 154/384 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs550993731, COSV68351359; called by muse, mutect2, varscan2
- CFAP57 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 188/429 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749165112; called by muse, mutect2, varscan2
- CFAP65 | c.396G>T p.K132N (on ENST00000341552 / NM_194302.4; = p.K67N on NM_152389.4) | Missense Mutation (SNP) | VAF 155/372 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV55391815; called by muse, mutect2, varscan2
- CFAP74 | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 168/358 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs376185684; called by muse, mutect2
- CFAP91 | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 178/407 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142545565; called by muse, mutect2, varscan2
- CFHR1 | c.611C>A p.S204Y | Missense Mutation (SNP) | VAF 96/219 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57626879; called by muse, mutect2, varscan2
- CGAS | c.1525G>T p.E509* | Nonsense Mutation (SNP) | VAF 42/108 reads (39%) | catalogued as COSV64808868; called by muse, mutect2, varscan2
- CGNL1 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 242/513 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs149230436; called by muse, mutect2, varscan2
- CGNL1 | c.2012G>A p.R671Q | Missense Mutation (SNP) | VAF 136/320 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs772369065; called by muse, varscan2
- CHD2 | c.4711G>A p.D1571N | Missense Mutation (SNP) | VAF 112/245 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.2); catalogued as rs780123418; called by muse, mutect2, varscan2
- CHD4 | c.5318G>A p.R1773Q (on ENST00000357008 / NM_001363606.2; = p.R1784Q on NM_001273.5) | Missense Mutation (SNP) | VAF 103/217 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1438981469, COSV58898333; called by muse, mutect2, varscan2
- CHD5 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 240/458 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as rs777905560; called by muse, mutect2, varscan2
- CHD8 | c.5680C>T p.R1894W (on ENST00000646647 / NM_001170629.2; = p.R1615W on NM_020920.4) | Missense Mutation (SNP) | VAF 212/451 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs974840941; called by muse, mutect2, varscan2
- CHD8 | c.1444C>T p.R482* (on ENST00000646647 / NM_001170629.2; = p.R203* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 273/560 reads (49%) | catalogued as COSV67870230; called by muse, mutect2, varscan2
- CHKB | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 140/313 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs200919604, COSV56414909; ClinVar: uncertain significance; called by muse, varscan2
- CHMP4B | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 103/254 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.577); catalogued as rs1169126897; called by muse, mutect2, varscan2
- CHRDL1 | c.1005C>A p.F335L (on ENST00000372045; = p.F341L on NM_145234.4) | Missense Mutation (SNP) | VAF 214/438 reads (49%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV54326274; called by muse, mutect2, varscan2
- CHRM4 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 213/454 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.276); catalogued as rs780553103, COSV100708753; called by muse, mutect2, varscan2
- CHRNA2 | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 115/281 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs866092045, CM1414139, COSV53560290; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRNA5 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 121/283 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138253116; called by muse, mutect2, varscan2
- CHRNA7 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.531); catalogued as rs199504752, COSV60969372; called by mutect2, varscan2
- CHRNA9 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 161/382 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs139982841, CM1414136; called by muse, mutect2
- CHRNB3 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 99/232 reads (43%) | catalogued as rs75170626, COSV51497255; called by muse, mutect2, varscan2
- CHST11 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 183/481 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV57985987; called by muse, mutect2, varscan2
- CHSY1 | c.1633G>A p.D545N | Missense Mutation (SNP) | VAF 219/408 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as rs776069033, COSV54252183; called by muse, mutect2, varscan2
- CHTF18 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 259/536 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50100722; called by muse, mutect2, varscan2
- CIP2A | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767069025, COSV55418459; called by muse, mutect2, varscan2
- CISD1 | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 157/349 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.361); catalogued as COSV61704067; called by muse, mutect2, varscan2
- CISD3 | c.273G>T p.E91D | Missense Mutation (SNP) | VAF 323/652 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1353251564; called by muse, mutect2, varscan2
- CKAP2 | c.305C>A p.P102H (on ENST00000378037 / NM_001098525.2; = p.P101H on NM_018204.5) | Missense Mutation (SNP) | VAF 103/223 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51620833; called by muse, mutect2, varscan2
- CKM | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 196/409 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.3); catalogued as rs200170574, COSV55532790; called by muse, mutect2, varscan2
- CLASP1 | c.3583C>T p.R1195* | Nonsense Mutation (SNP) | VAF 101/266 reads (38%) | catalogued as COSV99754098; called by muse, mutect2, varscan2
- CLASP1 | c.1183C>A p.L395M | Missense Mutation (SNP) | VAF 93/200 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs371571878; called by muse, mutect2, varscan2
- CLASP2 | c.3938C>A p.S1313Y (on ENST00000359576; = p.S1312Y on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 105/271 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV56281402; called by muse, mutect2, varscan2
- CLCA4 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 168/366 reads (46%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.743); catalogued as rs369186095; called by muse, mutect2, varscan2
- CLCN1 | c.1890G>T p.Q630H | Missense Mutation (SNP) | VAF 144/356 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.092); catalogued as rs1302946040; called by muse, mutect2, varscan2
- CLEC5A | c.471G>T p.Q157H | Missense Mutation (SNP) | VAF 113/256 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV69397018; called by muse, mutect2, varscan2
- CLN6 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 152/365 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs558566289; called by muse, mutect2, varscan2
- CMKLR1 | c.995C>A p.S332Y (on ENST00000312143 / NM_001142344.2; = p.S330Y on NM_004072.3) | Missense Mutation (SNP) | VAF 197/425 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV56436276; called by muse, mutect2, varscan2
- CMYA5 | c.6539C>T p.S2180L | Missense Mutation (SNP) | VAF 130/357 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs757070351, COSV71409891; called by muse, mutect2, varscan2
- CMYA5 | c.6693G>T p.E2231D | Missense Mutation (SNP) | VAF 94/278 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV71405028; called by muse, mutect2, varscan2
- CNKSR1 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 148/330 reads (45%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.488); catalogued as rs754881477, COSV100836664; called by muse, mutect2, varscan2
- CNOT4 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 92/258 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.81); catalogued as rs1308899779, COSV59651637; called by muse, varscan2
- CNTNAP2 | c.3262C>T p.R1088* | Nonsense Mutation (SNP) | VAF 132/276 reads (48%) | catalogued as rs766777011, COSV62164786; called by muse, varscan2
- CNTNAP5 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 98/242 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757108906, COSV70486167; called by muse, varscan2
- CNTRL | c.808G>T p.E270* | Nonsense Mutation (SNP) | VAF 88/185 reads (48%) | catalogued as rs1229040329; called by muse, mutect2, varscan2
- COIL | c.276G>T p.E92D | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.051); catalogued as COSV53594424; called by muse, mutect2
- COL11A1 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 50/117 reads (43%) | catalogued as COSV100614907, COSV62176520, COSV62184186; called by mutect2, varscan2
- COL11A1 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.905); catalogued as rs1341498364, COSV62186825; called by muse, mutect2, varscan2
- COL14A1 | c.3358C>T p.R1120* | Nonsense Mutation (SNP) | VAF 118/226 reads (52%) | catalogued as rs779378321, COSV52852069, COSV52861310; called by muse, mutect2, varscan2
- COL15A1 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 129/251 reads (51%) | catalogued as COSV100897626; called by mutect2, varscan2
- COL1A2 | c.752C>A p.S251Y | Missense Mutation (SNP) | VAF 160/377 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as rs1387151592; called by muse, mutect2, varscan2
- COL1A2 | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 22/466 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs893210028; called by muse, mutect2
- COL1A2 | c.1984C>A p.L662I | Missense Mutation (SNP) | VAF 99/258 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.081); catalogued as COSV99799855; called by muse, mutect2, varscan2
- COL20A1 | c.2079C>A p.I693= | Splice Region (SNP) | VAF 242/457 reads (53%) | catalogued as COSV100491630; called by muse, mutect2, varscan2
- COL21A1 | c.863G>T p.R288I | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs770639332, COSV55161169, COSV55161225; called by muse, varscan2
- COL21A1 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 190/362 reads (52%) | catalogued as COSV55158041; called by muse, mutect2, varscan2
- COL24A1 | c.4835C>T p.S1612L | Missense Mutation (SNP) | VAF 183/428 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs773684520, COSV65314341; called by muse, mutect2, varscan2
- COL24A1 | c.3982C>A p.L1328I | Missense Mutation (SNP) | VAF 205/381 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV65304646, COSV65314258; called by muse, mutect2, varscan2
- COL27A1 | c.3040C>T p.R1014C | Missense Mutation (SNP) | VAF 259/581 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs752193524; called by muse, mutect2, varscan2
- COL2A1 | c.4204G>A p.E1402K | Missense Mutation (SNP) | VAF 205/393 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as rs759583931, COSV61528864; called by muse, mutect2, varscan2
- COL4A5 | c.4075C>T p.P1359S | Missense Mutation (SNP) | VAF 125/264 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV60356306; called by muse, mutect2, varscan2
- COL4A6 | c.3076C>T p.R1026W | Missense Mutation (SNP) | VAF 218/632 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs747433163, COSV57875864; called by muse, mutect2, varscan2
- COL5A1 | c.1591G>A p.D531N | Missense Mutation (SNP) | VAF 178/467 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.114); catalogued as rs779170635, COSV65669205; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A1 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 252/517 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.393); catalogued as rs200389937; called by muse, mutect2, varscan2
- COL6A5 | c.7504G>A p.D2502N (on ENST00000312481; = p.D2498N on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 155/324 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs752185068, COSV99593495; called by muse, mutect2, varscan2
- COL8A2 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 270/674 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as rs748713100, COSV100290885; called by muse, mutect2, varscan2
- COL9A1 | c.1309G>T p.E437* | Nonsense Mutation (SNP) | VAF 92/212 reads (43%) | catalogued as COSV57879746; called by muse, mutect2, varscan2
- COLEC12 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 40/492 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV68370156, COSV68372639; called by muse, mutect2
- COLGALT2 | c.1657G>T p.E553* | Nonsense Mutation (SNP) | VAF 33/702 reads (5%) | catalogued as COSV62300258; called by muse, mutect2
- COLGALT2 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 120/371 reads (32%) | catalogued as rs373361853, COSV62298805; called by muse, mutect2, varscan2
- COPB1 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 154/322 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs369909236; called by muse, varscan2
- COQ8A | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 315/917 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143816043; called by muse, mutect2, varscan2
- CP | c.1918G>T p.D640Y | Missense Mutation (SNP) | VAF 185/367 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as CD067161, CP025132, COSV52832203; called by muse, mutect2, varscan2
- CP | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 155/392 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as rs181428197; called by muse, mutect2, varscan2
- CP | c.1138G>T p.E380* | Nonsense Mutation (SNP) | VAF 102/409 reads (25%) | catalogued as COSV52829795; called by muse, mutect2, varscan2
- CPA1 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 231/449 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs148329227, COSV50575831; called by muse, mutect2, varscan2
- CPA4 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 98/257 reads (38%) | catalogued as COSV55983603, COSV55984811; called by muse, mutect2, varscan2
- CPAMD8 | c.2068G>T p.D690Y (on ENST00000651564; = p.D643Y on NM_015692.5) | Missense Mutation (SNP) | VAF 125/353 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs984206466, COSV104394330, COSV52237125; called by muse, mutect2, varscan2
- CPB1 | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 192/387 reads (50%) | catalogued as rs772369161; called by muse, mutect2, varscan2
- CPB2 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 94/237 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as rs376421547; called by muse, mutect2, varscan2
- CPD | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 122/245 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs749464593, COSV99852783; called by muse, mutect2, varscan2
- CPSF4 | c.306C>T p.F102= | Splice Region (SNP) | VAF 147/301 reads (49%) | catalogued as rs767880639; called by muse, mutect2, varscan2
- CPT1C | c.223C>A p.L75I | Missense Mutation (SNP) | VAF 157/396 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV54919422; called by muse, mutect2, varscan2
- CRACDL | c.136C>A p.P46T | Missense Mutation (SNP) | VAF 193/412 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.111); catalogued as COSV67406441; called by muse, mutect2, varscan2
- CRB2 | c.3274G>A p.E1092K | Missense Mutation (SNP) | VAF 371/756 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as rs542637649; called by muse, mutect2, varscan2
- CREBBP | c.2264G>T p.S755I | Missense Mutation (SNP) | VAF 188/357 reads (53%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.618); catalogued as COSV104387923; called by muse, mutect2, varscan2
- CRISPLD1 | c.533G>T p.R178I | Missense Mutation (SNP) | VAF 97/233 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51552857; called by muse, mutect2, varscan2
- CRNN | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 142/627 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs184532873; called by muse, mutect2
- CROCC2 | c.4842G>T p.Q1614H | Missense Mutation (SNP) | VAF 178/457 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs1345254591; called by muse, mutect2, varscan2
- CRYBG2 | c.4213G>A p.E1405K | Missense Mutation (SNP) | VAF 169/341 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1203773831, COSV57485573; called by muse, mutect2, varscan2
- CRYBG3 | c.3117G>T p.K1039N | Missense Mutation (SNP) | VAF 74/210 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as rs545501003; called by mutect2, varscan2
- CSMD1 | c.4317C>A p.F1439L (on ENST00000520002; = p.F1438L on NM_033225.6) | Missense Mutation (SNP) | VAF 180/356 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.68); catalogued as COSV59298436; called by muse, mutect2, varscan2
- CSMD2 | c.9434C>A p.S3145Y | Missense Mutation (SNP) | VAF 20/351 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV53874473, COSV53882363; called by muse, mutect2
- CSMD2 | c.9207C>A p.F3069L | Missense Mutation (SNP) | VAF 120/261 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV53913629; called by muse, mutect2, varscan2
- CSMD2 | c.8389C>T p.R2797W | Missense Mutation (SNP) | VAF 265/561 reads (47%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.927); catalogued as rs746116665, COSV53890915; called by muse, mutect2, varscan2
- CSMD2 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 180/396 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs1391408280, COSV53878811; called by muse, mutect2
- CSMD3 | c.2032G>A p.D678N (on ENST00000297405 / NM_001363185.1; = p.D574N on NM_052900.3) | Missense Mutation (SNP) | VAF 102/234 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.418); catalogued as rs142207091, COSV99838134; called by muse, mutect2, varscan2
- CSNK1D | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 119/255 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs774858511, COSV53925579; called by muse, mutect2, varscan2
- CSNK2A1 | c.997C>T p.R333* | Nonsense Mutation (SNP) | VAF 155/345 reads (45%) | catalogued as COSV104372006; called by muse, mutect2, varscan2
- CST11 | c.260T>C p.V87A | Missense Mutation (SNP) | VAF 157/302 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV100983564; called by muse, mutect2, varscan2
- CTAGE1 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 95/202 reads (47%) | catalogued as COSV66943266; called by muse, mutect2, varscan2
- CTAGE9 | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 128/274 reads (47%) | catalogued as COSV58418616; called by mutect2, varscan2
- CTCFL | c.1800G>T p.K600N | Missense Mutation (SNP) | VAF 161/399 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV54778947; called by muse, mutect2, varscan2
- CTDP1 | c.1961C>T p.T654M | Missense Mutation (SNP) | VAF 322/606 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777623040, COSV50001698; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA2 | c.2258C>A p.S753Y | Missense Mutation (SNP) | VAF 161/339 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58153166; called by muse, mutect2, varscan2
- CTNND1 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 192/438 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1406000983, COSV62383129, COSV62384953; called by muse, mutect2, varscan2
- CTNS | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 131/294 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.238); catalogued as rs555311279, COSV50439978; called by muse, mutect2, varscan2
- CTSC | c.1172C>T p.T391I | Missense Mutation (SNP) | VAF 232/460 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs1324949386; called by muse, mutect2, varscan2
- CTSH | c.790A>G p.T264A | Missense Mutation (SNP) | VAF 88/233 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs1307842406; called by muse, mutect2, varscan2
- CTTNBP2 | c.3703G>A p.E1235K | Missense Mutation (SNP) | VAF 85/236 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as rs1317214891; called by muse, mutect2, varscan2
- CUBN | c.590A>G p.Y197C | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64701968; called by muse, mutect2, varscan2
- CUL2 | c.2083C>T p.R695W | Missense Mutation (SNP) | VAF 129/265 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs749443608, COSV66078880; called by muse, mutect2, varscan2
- CWC22 | c.2516G>A p.R839Q | Missense Mutation (SNP) | VAF 132/254 reads (52%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.921); catalogued as rs200967500; called by muse, mutect2, varscan2
- CWC27 | c.600-1G>T p.X200_splice | Splice Site (SNP) | VAF 42/114 reads (37%) | catalogued as COSV101126463; called by muse, mutect2, varscan2
- CYB561D1 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 230/479 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs1234971236, COSV100149777; called by muse, varscan2
- CYB5D1 | c.398C>A p.A133D | Missense Mutation (SNP) | VAF 163/365 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as COSV99641878; called by muse, mutect2, varscan2
- CYP17A1 | c.159C>A p.F53L | Missense Mutation (SNP) | VAF 186/421 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.116); catalogued as COSV64004932; called by muse, varscan2
- CYP2A13 | c.1228G>T p.D410Y | Missense Mutation (SNP) | VAF 134/282 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); catalogued as rs780068442; called by muse, mutect2, varscan2
- CYP2A6 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 178/410 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs773401076; called by muse, varscan2
- CYP2C18 | c.1229G>A p.G410D | Missense Mutation (SNP) | VAF 177/335 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as COSV99608712; called by muse, mutect2, varscan2
- CYP2J2 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 197/411 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs774331140, COSV64607342; called by muse, mutect2, varscan2
- CYP2J2 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 66/146 reads (45%) | catalogued as rs899892667, COSV64605512; called by mutect2, varscan2
- CYP2U1 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 275/638 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as COSV60549626; called by muse, mutect2, varscan2
- CYP2W1 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 184/562 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1322251139, COSV58269364, COSV58271220; called by muse, mutect2
- CYP3A4 | c.383G>T p.R128I | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV60504759; called by muse, mutect2, varscan2
- CYP4X1 | c.1512G>T p.K504N | Missense Mutation (SNP) | VAF 82/182 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV64150677; called by muse, varscan2
- CYP8B1 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 262/545 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs762230983, COSV60226483; called by muse, mutect2, varscan2
- CYRIA | c.855A>C p.K285N | Missense Mutation (SNP) | VAF 226/445 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as COSV62864409, COSV62865839, COSV62867483; called by muse, mutect2, varscan2
- DAB2IP | c.493C>A p.L165I (on ENST00000408936; = p.L137I on NM_032552.3) | Missense Mutation (SNP) | VAF 223/441 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52256933; called by muse, mutect2, varscan2
- DACT1 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 228/441 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs776160196, COSV60020789; called by muse, mutect2, varscan2
- DACT1 | c.2180C>T p.S727L | Missense Mutation (SNP) | VAF 280/555 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60023876; called by muse, mutect2, varscan2
- DAO | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 116/265 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201583577; called by muse, mutect2, varscan2
- DAPK1 | c.1996C>T p.R666* | Nonsense Mutation (SNP) | VAF 165/363 reads (45%) | catalogued as COSV100800726; called by muse, mutect2, varscan2
- DBF4B | c.761C>A p.S254Y | Missense Mutation (SNP) | VAF 146/279 reads (52%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as rs774436262, COSV59258932, COSV59261867; called by muse, mutect2, varscan2
- DBH | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 213/486 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs368994366; called by muse, mutect2, varscan2
- DCAF10 | c.1037G>T p.R346I | Missense Mutation (SNP) | VAF 91/171 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV54287205, COSV99647540; called by muse, mutect2, varscan2
- DCAF13 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 142/282 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1425272025, COSV52570614; called by muse, mutect2, varscan2
- DCAF4L1 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 166/353 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1224359974, COSV60787139; called by muse, mutect2, varscan2
- DCAF4L2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 139/419 reads (33%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs1202467100, COSV100151058, COSV60479030; called by muse, mutect2, varscan2
- DCAF6 | c.2242C>T p.R748W (on ENST00000312263 / NM_001349778.1; = p.R768W on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 167/630 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs745724831; called by muse, varscan2
- DCAF8L1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 298/623 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs767977769, COSV71595101; called by muse, mutect2, varscan2
- DCBLD1 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1323940181, COSV51643514; called by muse, mutect2, varscan2
- DCC | c.3062G>A p.R1021Q | Missense Mutation (SNP) | VAF 100/301 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as rs370927048; called by muse, mutect2
- DCLK2 | c.30G>T p.E10D | Missense Mutation (SNP) | VAF 115/352 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99651752; called by muse, mutect2, varscan2
- DCLK2 | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 210/410 reads (51%) | catalogued as COSV56200287; called by muse, mutect2, varscan2
- DCLRE1A | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 160/308 reads (52%) | catalogued as rs1212761218, COSV100800363; called by muse, mutect2, varscan2
- DCLRE1B | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 65/190 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767629462, COSV99871199; called by muse, varscan2
- DCSTAMP | c.1347C>A p.F449L | Missense Mutation (SNP) | VAF 85/187 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV52575994; called by muse, mutect2, varscan2
- DCT | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 155/430 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs759177137, COSV65468582; called by muse, mutect2, varscan2
- DCTN3 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 118/219 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0.063); catalogued as rs765619518; called by muse, mutect2, varscan2
- DDX10 | c.1456G>T p.E486* | Nonsense Mutation (SNP) | VAF 78/154 reads (51%) | catalogued as COSV100489936; called by muse, mutect2, varscan2
- DDX17 | c.1819G>T p.E607* | Nonsense Mutation (SNP) | VAF 245/469 reads (52%) | catalogued as COSV53247135, COSV53249825; called by muse, mutect2, varscan2
- DDX17 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 125/338 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs1479771650, COSV53251749; called by muse, mutect2, varscan2
- DDX20 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 112/276 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as rs773108633, COSV63831036; called by muse, mutect2, varscan2
- DDX23 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 205/410 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV56397324; called by muse, varscan2
- DDX24 | c.1387C>T p.R463W | Missense Mutation (SNP) | VAF 20/351 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs201694454, COSV58212393; called by muse, mutect2
- DDX31 | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 135/326 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754917433, COSV64649948; called by muse, mutect2, varscan2
- DDX53 | c.590G>T p.R197I | Missense Mutation (SNP) | VAF 220/490 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60070174; called by muse, mutect2, varscan2
- DEDD | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 189/641 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs754848698, COSV63502143; called by muse, mutect2, varscan2
- DENND1C | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 132/283 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1293375435; called by muse, varscan2
- DENND5A | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 271/602 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs369437857; called by muse, mutect2, varscan2
- DEPDC1B | c.1582C>T p.R528* | Nonsense Mutation (SNP) | VAF 83/209 reads (40%) | catalogued as rs575323127, COSV54009042; called by muse, mutect2, varscan2
- DEPDC1B | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs201451342, COSV54013086; called by muse, mutect2, varscan2
- DERL2 | c.238C>A p.R80S | Missense Mutation (SNP) | VAF 101/236 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50148031; called by mutect2, varscan2
- DGAT2 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 159/325 reads (49%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.957); catalogued as rs545718921; called by muse, mutect2, varscan2
- DGAT2L6 | c.742dup p.T248Nfs*50 | Frame Shift Ins (INS) | VAF 166/756 reads (22%) | catalogued as rs760082718; called by mutect2, pindel, varscan2
- DGKD | c.3301G>A p.E1101K (on ENST00000264057 / NM_152879.3; = p.E1057K on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 132/258 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.107); catalogued as rs991285626; called by muse, varscan2
- DGKE | c.1498C>T p.R500* | Nonsense Mutation (SNP) | VAF 13/280 reads (5%) | catalogued as rs1342368899, COSV52349569; called by muse, mutect2
- DGKI | c.2382G>T p.E794D | Missense Mutation (SNP) | VAF 107/294 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs1377978333; called by muse, mutect2, varscan2
- DHCR24 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 134/282 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs767344296; called by muse, mutect2, varscan2
- DHFR | c.226C>A p.L76I | Missense Mutation (SNP) | VAF 58/106 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1456478807, COSV71485479; called by muse, mutect2, varscan2
- DHRS7C | c.449C>T p.A150V (on ENST00000330255 / NM_001220493.2; = p.A149V on NM_001105571.3) | Missense Mutation (SNP) | VAF 124/313 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs773513074; called by muse, mutect2, varscan2
- DHTKD1 | c.1999G>A p.D667N | Missense Mutation (SNP) | VAF 194/647 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs371485560; called by muse, mutect2, varscan2
- DHX40 | c.1913G>T p.R638I | Missense Mutation (SNP) | VAF 115/257 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV99232976; called by muse, mutect2, varscan2
- DHX9 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 76/296 reads (26%) | catalogued as rs865830988, COSV62358500; called by muse, varscan2
- DIAPH3 | c.3135G>T p.K1045N (on ENST00000400324 / NM_001042517.2; = p.K782N on NM_030932.3) | Missense Mutation (SNP) | VAF 15/242 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.304); catalogued as COSV57367236; called by muse, mutect2
- DIAPH3 | c.2698T>G p.F900V (on ENST00000400324 / NM_001042517.2; = p.F637V on NM_030932.3) | Missense Mutation (SNP) | VAF 131/277 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757481645; called by mutect2, varscan2
- DIPK2B | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 281/598 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs746307645; called by muse, mutect2, varscan2
- DIRAS3 | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 23/607 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV63970713; called by muse, mutect2
- DIS3 | c.296G>T p.R99I | Missense Mutation (SNP) | VAF 162/368 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs763490458, COSV58328266; called by muse, mutect2, varscan2
- DISP1 | c.4202C>T p.S1401L | Missense Mutation (SNP) | VAF 155/613 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV52654754; called by muse, mutect2, varscan2
- DIXDC1 | c.341C>A p.S114Y | Missense Mutation (SNP) | VAF 128/281 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59462864; called by muse, varscan2
- DIXDC1 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 120/262 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs1027236169, COSV100180031, COSV59460966; called by muse, varscan2
- DLC1 | c.2338G>A p.D780N (on ENST00000276297 / NM_001348081.2; = p.D343N on NM_006094.5) | Missense Mutation (SNP) | VAF 259/500 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV52300754; called by muse, varscan2
- DLEC1 | c.4048G>T p.E1350* | Nonsense Mutation (SNP) | VAF 29/434 reads (7%) | catalogued as COSV57294968; called by muse, mutect2
- DLGAP5 | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 78/216 reads (36%) | catalogued as rs774608538, COSV55962038; called by muse, mutect2, varscan2
- DMRT3 | c.581G>A p.S194N | Missense Mutation (SNP) | VAF 174/392 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.526); catalogued as rs763720874; called by muse, mutect2, varscan2
- DMTN | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 182/360 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1371569595, COSV56111740; called by muse, mutect2, varscan2
- DMXL1 | c.6125G>A p.R2042H | Missense Mutation (SNP) | VAF 105/205 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1339119066, COSV60705408; called by muse, mutect2, varscan2
- DMXL2 | c.278G>T p.R93I | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as COSV99195926; called by muse, mutect2, varscan2
- DNAAF2 | c.2381C>T p.T794M | Missense Mutation (SNP) | VAF 92/225 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs185361306, COSV53566940; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH1 | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 149/318 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs938070698, COSV101325736; called by muse, mutect2, varscan2
- DNAH11 | c.4670G>A p.R1557Q | Missense Mutation (SNP) | VAF 126/289 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs1166407911, COSV100178473, COSV60966002; called by muse, mutect2, varscan2
- DNAH12 | c.3673C>T p.R1225* (on ENST00000351747; = p.R1248* on NM_001366028.2) | Nonsense Mutation (SNP) | VAF 100/217 reads (46%) | catalogued as rs981533821; called by muse, mutect2, varscan2
- DNAH12 | c.2781G>T p.Q927H (on ENST00000351747; = p.Q950H on NM_001366028.2) | Missense Mutation (SNP) | VAF 177/373 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100696182; called by muse, mutect2, varscan2
- DNAH14 | c.5344C>T p.R1782C (on ENST00000445597; = p.R2187C on NM_001367479.1) | Missense Mutation (SNP) | VAF 125/407 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs993935877, COSV59899326; called by muse, mutect2, varscan2
- DNAH17 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 143/312 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs768308901, COSV101102013, COSV67758449; called by muse, mutect2, varscan2
- DNAH2 | c.2510G>A p.R837H | Missense Mutation (SNP) | VAF 205/435 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs779653586, COSV101209097; called by muse, mutect2, varscan2
- DNAH3 | c.8904G>T p.E2968D | Missense Mutation (SNP) | VAF 236/470 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104372710; called by muse, mutect2, varscan2
- DNAH3 | c.8179G>T p.E2727* | Nonsense Mutation (SNP) | VAF 54/574 reads (9%) | catalogued as COSV54534050; called by muse, mutect2
- DNAH3 | c.2563A>G p.T855A | Missense Mutation (SNP) | VAF 149/313 reads (48%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1429801892; called by muse, mutect2, varscan2
- DNAH5 | c.5776G>A p.E1926K | Missense Mutation (SNP) | VAF 120/326 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs771222700, COSV54202729, COSV99454399; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH6 | c.8677C>T p.R2893* | Nonsense Mutation (SNP) | VAF 159/364 reads (44%) | catalogued as rs552500475, COSV52850352; called by muse, mutect2, varscan2
- DNAH7 | c.6223C>A p.L2075I | Missense Mutation (SNP) | VAF 149/322 reads (46%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.612); catalogued as rs1338784675, COSV56781678; called by muse, mutect2, varscan2
- DNAH7 | c.2660G>A p.R887Q | Missense Mutation (SNP) | VAF 144/297 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs780057760, COSV56758361; called by muse, mutect2, varscan2
- DNAH7 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 99/234 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs770564417; called by muse, mutect2, varscan2
- DNAH8 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 121/242 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.186); catalogued as rs138901149; called by muse, mutect2, varscan2
- DNAI4 | c.1870C>T p.R624* | Nonsense Mutation (SNP) | VAF 80/181 reads (44%) | catalogued as rs758550177, COSV64022904; called by muse, mutect2, varscan2
- DNAJA1 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 169/345 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as rs141132012; called by muse, mutect2, varscan2
- DNAJB1 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 129/246 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs765857048; called by muse, mutect2, varscan2
- DNAJB5 | c.268T>G p.F90V | Missense Mutation (SNP) | VAF 46/602 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100258082; called by muse, mutect2
- DNAJC13 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 136/288 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs547360849, COSV53446557; called by muse, mutect2, varscan2
- DNAJC13 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 114/240 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs202069439; called by muse, mutect2, varscan2
- DNAJC27 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 180/384 reads (47%) | catalogued as rs1192797296, COSV53093961; called by muse, varscan2
- DNAJC7 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 113/218 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1346751595, COSV57267880; called by muse, mutect2, varscan2
- DNAL1 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 146/336 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.02); catalogued as COSV60727344; called by muse, mutect2, varscan2
- DNER | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 20/421 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV59163522; called by muse, mutect2
- DNM3 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 132/444 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766159947, COSV62458116; called by muse, mutect2, varscan2
- DNMBP | c.3254G>A p.R1085H | Missense Mutation (SNP) | VAF 134/291 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs759738167, COSV60624289; called by muse, mutect2, varscan2
- DOCK10 | c.1229C>T p.T410M | Missense Mutation (SNP) | VAF 104/239 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); catalogued as rs775343177; called by muse, mutect2, varscan2
- DOCK11 | c.4120G>T p.E1374* | Nonsense Mutation (SNP) | VAF 266/490 reads (54%) | catalogued as COSV99354069; called by muse, mutect2, varscan2
- DOCK2 | c.2513C>A p.S838Y | Missense Mutation (SNP) | VAF 137/327 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56975150; called by muse, mutect2, varscan2
- DOCK3 | c.1009G>T p.E337* | Nonsense Mutation (SNP) | VAF 115/300 reads (38%) | catalogued as COSV56522566; called by muse, mutect2, varscan2
- DOCK4 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 110/250 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.709); catalogued as rs868046387; called by muse, mutect2, varscan2
- DOCK6 | c.4738G>A p.D1580N | Missense Mutation (SNP) | VAF 130/308 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762402181; called by muse, mutect2, varscan2
- DOCK6 | c.4159G>A p.E1387K | Missense Mutation (SNP) | VAF 126/330 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs374869280; called by muse, varscan2
- DOCK8 | c.6097C>T p.R2033C | Missense Mutation (SNP) | VAF 130/264 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs751058288, COSV66619972; called by muse, mutect2, varscan2
- DOP1A | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 72/187 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1468093035; called by muse, mutect2, varscan2
- DPPA3 | c.285G>T p.K95N | Missense Mutation (SNP) | VAF 119/308 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV61502790; called by muse, mutect2, varscan2
- DPYD | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 111/285 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs777560627, COSV64603563; called by muse, mutect2, varscan2
- DRC7 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 154/154 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs373094122; called by muse, mutect2, varscan2
- DSCC1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 124/241 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as rs144655317; called by muse, mutect2, varscan2
- DSEL | c.3098C>T p.S1033L | Missense Mutation (SNP) | VAF 241/472 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100025957, COSV59494476; called by muse, mutect2, varscan2
- DSG1 | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 67/129 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767678194, COSV57133741; called by muse, mutect2, varscan2
- DSG3 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 87/175 reads (50%) | catalogued as rs1472943015, COSV57125252, COSV99934677; called by muse, mutect2, varscan2
- DST | c.20063C>A p.T6688N (on ENST00000361203 / NM_001374722.1; = p.T4385N on NM_015548.5) | Missense Mutation (SNP) | VAF 115/231 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99759071; called by muse, mutect2, varscan2
- DST | c.2489G>A p.R830Q (on ENST00000361203 / NM_001374722.1; = p.R504Q on NM_001723.6) | Missense Mutation (SNP) | VAF 94/218 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762435098; called by muse, varscan2
- DTL | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 73/337 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65341886; called by muse, mutect2, varscan2
- DTL | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 235/749 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs778583842; called by muse, mutect2, varscan2
- DUSP16 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 242/552 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as rs779032871; called by muse, mutect2, varscan2
- DUSP9 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 296/663 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); catalogued as rs138533897; called by muse, mutect2, varscan2
- DUT | c.646C>T p.R216* (on ENST00000331200 / NM_001025248.2; = p.R128* on NM_001948.4) | Nonsense Mutation (SNP) | VAF 95/214 reads (44%) | catalogued as rs989363911; called by muse, mutect2, varscan2
- DYNC1H1 | c.12076G>A p.D4026N | Missense Mutation (SNP) | VAF 169/349 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.196); catalogued as rs768636289, COSV64140358; called by muse, mutect2, varscan2
- DYNC2H1 | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 81/173 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs561232842, COSV62086954; ClinVar: likely benign; called by muse, mutect2, varscan2
- DYNC2H1 | c.4391T>C p.V1464A | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100519935; called by muse, mutect2, varscan2
- DYNC2H1 | c.6044G>A p.R2015Q | Missense Mutation (SNP) | VAF 173/367 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs775984088, COSV62091815; called by muse, varscan2
- DYNC2I1 | c.1815G>T p.E605D | Missense Mutation (SNP) | VAF 148/321 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751206395; called by muse, mutect2, varscan2
- DYNLT3 | c.219G>T p.K73N | Missense Mutation (SNP) | VAF 186/348 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV66078739; called by mutect2, varscan2
- DYRK1A | c.1556C>T p.S519L | Missense Mutation (SNP) | VAF 116/272 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs556482236, COSV100117324; called by muse, mutect2, varscan2
- DYRK3 | c.1115C>A p.S372Y | Missense Mutation (SNP) | VAF 167/618 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100895639; called by muse, varscan2
- DYSF | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 143/328 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.212); catalogued as rs886043461; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYTN | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 140/295 reads (47%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs369410820; called by muse, mutect2, varscan2
- EBF2 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 166/331 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV68776583, COSV68780548; called by muse, varscan2
- ECE1 | c.1620C>A p.F540L | Missense Mutation (SNP) | VAF 137/326 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as COSV99941319; called by muse, mutect2
- ECE2 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 219/434 reads (50%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs768830091; called by muse, mutect2, varscan2
- ECH1 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 221/459 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.271); catalogued as rs1403167483; called by muse, mutect2, varscan2
- ECT2L | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 149/362 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs754540928, COSV62882962; called by muse, mutect2, varscan2
- EDN2 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 244/518 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs926556784, COSV65423371; called by muse, varscan2
- EDRF1 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 200/387 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.172); catalogued as COSV61766493; called by muse, mutect2, varscan2
- EEA1 | c.999G>T p.K333N | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV59287992; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 130/292 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs748024573, COSV66964361; called by muse, varscan2
- EEF2K | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 110/243 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs779040918; called by muse, mutect2, varscan2
- EFCAB13 | c.2792C>T p.S931L | Missense Mutation (SNP) | VAF 92/187 reads (49%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.024); catalogued as rs369709542, COSV58946115; called by muse, mutect2, varscan2
- EFCAB9 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 153/366 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs902161328, COSV67960724; called by muse, mutect2, varscan2
- EFHC1 | c.1625C>T p.A542V | Missense Mutation (SNP) | VAF 299/620 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs766799700; called by muse, mutect2, varscan2
- EFR3A | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 94/184 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs1291653738, COSV54459529; called by muse, mutect2, varscan2
- EFS | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 301/562 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs905331434; called by muse, mutect2, varscan2
- EGF | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 89/209 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.116); catalogued as rs147634717, COSV54486379; called by muse, mutect2, varscan2
- EGFLAM | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 128/270 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as rs745930197, COSV59310512; called by muse, varscan2
- EGR2 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 291/591 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54347773; called by muse, mutect2, varscan2
- EGR4 | c.626C>T p.S209L (on ENST00000545030; = p.S106L on NM_001965.4) | Missense Mutation (SNP) | VAF 256/589 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs1296996754; called by muse, mutect2, varscan2
- EHBP1 | c.3593C>T p.A1198V | Missense Mutation (SNP) | VAF 141/314 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV99859721; called by muse, mutect2, varscan2
- EHD4 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 145/303 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs958957223; called by muse, mutect2, varscan2
- EHF | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 147/278 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757126229, COSV57669499; called by muse, mutect2, varscan2
- EIF4B | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.868); catalogued as COSV100016747; called by muse, mutect2, varscan2
- EIF4B | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 159/431 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV50401823; called by muse, mutect2, varscan2
- EIF4E2 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 276/661 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as rs925320031; called by muse, mutect2, varscan2
- EIF4EBP1 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 156/319 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs751889248, COSV58774236; called by muse, mutect2, varscan2
- EIF4G2 | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 118/314 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.067); catalogued as rs1201787120; called by muse, mutect2, varscan2
- ELAC2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as rs779607134, COSV62034578; called by muse, mutect2, varscan2
- ELOA | c.818C>A p.S273Y | Missense Mutation (SNP) | VAF 170/353 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV69311329; called by muse, mutect2, varscan2
- ELOA | c.1807C>A p.L603I | Missense Mutation (SNP) | VAF 134/301 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV99072567; called by muse, mutect2, varscan2
- ELOVL1 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 199/430 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201270403; called by muse, mutect2, varscan2
- EMC2 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as rs1030080319; called by muse, mutect2, varscan2
- EMD | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 136/301 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as CD078077, COSV63962464; called by muse, mutect2, varscan2
- EML3 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 305/640 reads (48%) | catalogued as COSV53882422; called by muse, mutect2, varscan2
- ENAM | c.3263C>T p.T1088M | Missense Mutation (SNP) | VAF 201/426 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs139404568; called by muse, mutect2, varscan2
- ENDOD1 | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 145/310 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773730577; called by muse, mutect2, varscan2
- ENKUR | c.314T>G p.F105C | Missense Mutation (SNP) | VAF 144/283 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58633152; called by muse, mutect2, varscan2
- ENO1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 218/441 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs371689591; called by muse, mutect2, varscan2
- ENO2 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 179/385 reads (46%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs782101405; called by muse, mutect2, varscan2
- ENOX2 | c.1108C>T p.R370C (on ENST00000338144 / NM_001382520.1; = p.R341C on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs199818795, COSV57650385; called by muse, mutect2, varscan2
- ENPEP | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 251/486 reads (52%) | catalogued as rs143343563, COSV54448047; called by muse, mutect2, varscan2
- ENPEP | c.2672G>A p.R891Q | Missense Mutation (SNP) | VAF 111/259 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770598233, COSV54448376; called by muse, mutect2, varscan2
- EOLA2 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 398/880 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.055); catalogued as rs144047890; called by muse, mutect2
- EP300 | c.1702C>T p.R568W | Missense Mutation (SNP) | VAF 146/373 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1046073854, COSV54325115; called by muse, varscan2
- EP300 | c.1739G>A p.R580Q | Missense Mutation (SNP) | VAF 137/274 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54329321; called by muse, varscan2
- EP400 | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 141/270 reads (52%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.654); catalogued as rs766432250, COSV57780225; called by muse, mutect2, varscan2
- EPAS1 | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 19/305 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55388635; called by muse, mutect2
- EPB41L3 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 22/513 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs1392021881, COSV59453407; called by muse, mutect2
- EPB41L4A | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 142/342 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.559); catalogued as rs772237814, COSV54863025; called by muse, varscan2
- EPB41L5 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 103/228 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1414991675, COSV55354222; called by muse, mutect2, varscan2
- EPC1 | c.2266C>T p.R756* | Nonsense Mutation (SNP) | VAF 164/430 reads (38%) | catalogued as rs1218639286; called by muse, mutect2, varscan2
- EPHA5 | c.2950G>T p.E984* | Nonsense Mutation (SNP) | VAF 192/396 reads (48%) | catalogued as COSV99899142; called by muse, varscan2
- EPHA5 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 162/368 reads (44%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as rs151302542; called by muse, mutect2, varscan2
- EPHB1 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 156/337 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs764139128, COSV67657222, COSV67674992; called by muse, mutect2, varscan2
- EPM2AIP1 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 168/319 reads (53%) | SIFT tolerated (0.76); PolyPhen benign (0.05); catalogued as COSV51615868; called by muse, varscan2
- EPRS1 | c.897G>T p.M299I | Missense Mutation (SNP) | VAF 108/392 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV65097640; called by muse, mutect2, varscan2
- EPS15 | c.2569G>A p.E857K | Missense Mutation (SNP) | VAF 155/344 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs762929521; called by muse, mutect2, varscan2
- EPS15 | c.1816A>C p.S606R | Missense Mutation (SNP) | VAF 128/275 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as COSV65540465; called by muse, mutect2, varscan2
- EPS8 | c.1711C>T p.R571* | Nonsense Mutation (SNP) | VAF 115/276 reads (42%) | catalogued as rs1457535054, COSV55528972; called by muse, mutect2, varscan2
- ERAL1 | c.760C>T p.L254F | Missense Mutation (SNP) | VAF 189/369 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs767871960; called by muse, mutect2, varscan2
5,902 further variants in this file (4,291 protein-altering or splice-affecting, 1,326 silent, 285 other) are not listed here.
